Somatic mutation profile of tumor specimen TCGA-B5-A5OC-01A (aliquot TCGA-B5-A5OC-01A-21D-A27P-09) from TCGA case TCGA-B5-A5OC, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 71.5 years (26,109 days).
Specimen TCGA-B5-A5OC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7815e932-4ddc-4a1a-8b72-841d374e93ad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B5-A5OC-10A (Blood Derived Normal), aliquot TCGA-B5-A5OC-10A-01D-A27P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dc02ef62-0818-492f-8b5c-c0b892ebd2f8

The open-access MAF lists 1,265 somatic variants for this specimen: 945 protein-altering or splice-affecting, 291 silent, 29 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 638, Silent 291, Frame Shift Del 201, Frame Shift Ins 35, Nonsense Mutation 32, Splice Site 22, Splice Region 11, Intron 10, RNA 6, 5'UTR 6, 3'UTR 4, In Frame Del 4.

Variants (750 of 1,265; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.121A>G p.T41A | Missense Mutation (SNP) | VAF 21/89 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs121913412, COSV62687862, COSV62689580, COSV62714770; ClinVar: conflicting interpretations of pathogenicity / pathogenic /  other / likely pathogenic; called by muse, mutect2, varscan2
- IQSEC2 | c.848del p.G283Afs*23 (on ENST00000642864 / NM_001111125.3; = p.G78Afs*23 on NM_015075.2) | Frame Shift Del (DEL) | VAF 15/71 reads (21%) | catalogued as rs782660318, COSV64726734; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 13/77 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 18/69 reads (26%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- MYH11 | c.5787-4707del | Intron (DEL) | VAF 19/81 reads (23%) | catalogued as rs747392139, COSV100257523; ClinVar: uncertain significance / benign / likely benign / likely pathogenic; called by mutect2, varscan2
- MYO3A | c.2180dup p.N727Kfs*9 | Frame Shift Ins (INS) | VAF 18/78 reads (23%) | catalogued as rs769462859; ClinVar: likely pathogenic; called by mutect2, varscan2
- PKD1 | c.2494dup p.R832Pfs*40 | Frame Shift Ins (INS) | VAF 44/184 reads (24%) | catalogued as rs1567210630; ClinVar: pathogenic; called by mutect2, varscan2
- PTEN | c.276C>G p.D92E | Missense Mutation (SNP) | VAF 21/105 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM033666, COSV64288954, COSV64292660; called by muse, mutect2, varscan2
- PTEN | c.959del p.L320* | Frame Shift Del (DEL) | VAF 21/94 reads (22%) | hotspot (GDC flag); catalogued as rs1114167682; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- RYR1 | c.14344G>A p.G4782R | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746538672, CM1511009, COSV100615020, COSV100615387; ClinVar: uncertain significance / pathogenic; called by muse, varscan2
- TBCK | c.1370del p.N457Tfs*15 (on ENST00000273980 / NM_001163436.4; = p.N394Tfs*15 on NM_033115.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 12/72 reads (17%) | catalogued as rs746860249, CD164312; ClinVar: pathogenic; called by mutect2, varscan2
- ZIC1 | c.1165C>T p.Q389* | Nonsense Mutation (SNP) | VAF 20/87 reads (23%) | catalogued as rs1057517668, CM159366, COSV99291777; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AASDH | c.1319del p.L440Wfs*43 | Frame Shift Del (DEL) | VAF 20/62 reads (32%) | catalogued as rs770970036; called by mutect2, varscan2
- ABCA12 | c.5261C>A p.P1754H (on ENST00000272895 / NM_173076.3; = p.P1436H on NM_015657.3) | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99789406; called by muse, mutect2, varscan2
- ABCA3 | c.1415C>T p.A472V | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.632); catalogued as COSV100068304; called by mutect2, varscan2
- ABHD14A-ACY1 | c.1021del p.G341Vfs*17 | Frame Shift Del (DEL) | VAF 19/103 reads (18%) | catalogued as rs1559780036; called by mutect2, pindel, varscan2
- ABHD3 | c.1112C>A p.S371Y | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV100004305, COSV56677141; called by muse, mutect2, varscan2
- ABHD5 | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV99185462; called by muse, mutect2, varscan2
- ABL2 | c.889G>A p.G297S (on ENST00000502732 / NM_007314.4; = p.G282S on NM_005158.5) | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100772632, COSV61020685; called by muse, mutect2, varscan2
- ABRA | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs200193774, COSV61731940; called by muse, mutect2, varscan2
- AC109583.1 | c.47C>T p.T16M | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100167847; called by muse, mutect2
- ACACB | c.2575C>T p.L859F | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1210793795, COSV100622692; called by muse, mutect2, varscan2
- ACACB | c.6881C>T p.A2294V | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs139826793; called by muse, mutect2, varscan2
- ACADVL | c.1775G>T p.G592V | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV50036275, COSV99138433; called by muse, mutect2, varscan2
- ACOT12 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100296865; called by muse, mutect2, varscan2
- ACOX2 | c.1607C>T p.T536I | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.296); catalogued as COSV100250100; called by muse, mutect2
- ACSM2A | c.740G>A p.G247D (on ENST00000219054; = p.G168D on NM_001308169.2) | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.105); catalogued as COSV54583314; called by muse, mutect2, varscan2
- ACTG2 | c.85del p.R29Gfs*16 | Frame Shift Del (DEL) | VAF 19/87 reads (22%) | catalogued as rs751325833; called by mutect2, pindel, varscan2
- ACTN4 | c.2437C>T p.R813C | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs755524840, COSV99400031; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 15/80 reads (19%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ACVRL1 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.67); catalogued as rs756447582, COSV101187847; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACVRL1 | c.1226C>T p.A409V | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.57); catalogued as COSV101187850; called by muse, mutect2, varscan2
- ACYP1 | c.187C>T p.Q63* | Nonsense Mutation (SNP) | VAF 27/113 reads (24%) | catalogued as COSV53135420, COSV99464973; called by muse, mutect2, varscan2
- ADAM12 | c.937G>T p.G313W | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100900261; called by muse, mutect2, varscan2
- ADAM23 | c.2340dup p.K781Qfs*3 | Frame Shift Ins (INS) | VAF 14/83 reads (17%) | catalogued as rs767549806; called by mutect2, varscan2
- ADAM28 | c.1104-1G>T p.X368_splice | Splice Site (SNP) | VAF 18/115 reads (16%) | catalogued as COSV99738378; called by muse, mutect2, varscan2
- ADAM30 | c.1024C>A p.H342N | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101023820; called by muse, mutect2, varscan2
- ADAMTS14 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs780210737, COSV64600981; called by muse, mutect2, varscan2
- ADAMTS14 | c.2450G>C p.G817A | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as COSV100941498; called by muse, mutect2, varscan2
- ADAMTS20 | c.1445G>A p.R482Q | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs191978295, COSV67134703; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2885T>C p.L962P | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs1447598120, COSV99647043; called by muse, mutect2
- ADAR | c.2263G>A p.E755K | Missense Mutation (SNP) | VAF 61/126 reads (48%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as rs758150130, COSV52720654; called by muse, mutect2, varscan2
- ADARB2 | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV101186827; called by muse, mutect2
- ADGRA2 | c.880G>A p.A294T | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs770329796, COSV100177804; called by muse, mutect2
- ADGRE1 | c.2290A>G p.I764V | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.04); catalogued as COSV99165178; called by muse, mutect2, varscan2
- ADNP | c.3047del p.K1016Rfs*11 | Frame Shift Del (DEL) | VAF 18/94 reads (19%) | catalogued as rs761350619; called by mutect2, varscan2
- ADRA1D | c.523G>A p.V175M | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as COSV101062951; called by muse, mutect2, varscan2
- ADSS2 | c.728A>G p.H243R | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs778380869, COSV100836829; called by muse, mutect2, varscan2
- AFF2 | c.3742A>G p.N1248D | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99663209; called by muse, mutect2, varscan2
- AGAP1 | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs367559858, COSV58328453; called by muse, mutect2, varscan2
- AGAP1 | c.2072A>C p.E691A (on ENST00000304032 / NM_001037131.3; = p.E638A on NM_014914.5) | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0.114); catalogued as COSV100364624; called by muse, mutect2, varscan2
- AHNAK | c.14361A>T p.K4787N | Missense Mutation (SNP) | VAF 58/255 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV57211597, COSV99946822; called by muse, mutect2
- AHNAK | c.14359A>T p.K4787* | Nonsense Mutation (SNP) | VAF 58/252 reads (23%) | catalogued as COSV99946825; called by muse, mutect2
- AHNAK2 | c.5773del p.Q1925Rfs*11 | Frame Shift Del (DEL) | VAF 29/190 reads (15%) | catalogued as rs1566912199; called by mutect2, pindel, varscan2
- AIDA | c.482C>A p.P161Q | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV100388181; called by muse, mutect2
- AKAP9 | c.6662C>T p.A2221V (on ENST00000359028; = p.A2197V on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100662245; called by muse, mutect2, varscan2
- ALDH1A3 | c.670G>A p.G224R | Missense Mutation (SNP) | VAF 40/159 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as rs377673187; called by muse, mutect2, varscan2
- ALDH2 | c.864dup p.K289Efs*45 | Frame Shift Ins (INS) | VAF 20/81 reads (25%) | catalogued as rs771889973; called by mutect2, varscan2
- AMY2A | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 38/594 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as rs750768619, COSV70215035; called by muse, mutect2
- ANGPTL2 | c.453C>A p.N151K | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.791); catalogued as COSV99401386; called by muse, mutect2, varscan2
- ANGPTL3 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV99223881; called by muse, mutect2
- ANK1 | c.1282dup p.A428Gfs*43 | Frame Shift Ins (INS) | VAF 9/48 reads (19%) | catalogued as rs769735016; called by mutect2, pindel, varscan2
- ANKRD1 | c.643C>T p.R215* | Nonsense Mutation (SNP) | VAF 11/67 reads (16%) | catalogued as COSV100865315; called by muse, mutect2, varscan2
- ANKRD12 | c.2169del p.K723Nfs*45 | Frame Shift Del (DEL) | VAF 5/24 reads (21%) | catalogued as rs1469889281; called by mutect2, varscan2
- ANKRD20A4P | c.1376del p.N459Ifs*5 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | catalogued as rs749182271; called by mutect2, varscan2
- ANKRD34B | c.1249G>T p.G417C | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.62); catalogued as COSV100103359, COSV100103488; called by muse, mutect2, varscan2
- ANOS1 | c.1581G>T p.K527N | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.372); catalogued as COSV99390752; called by muse, mutect2, varscan2
- ANPEP | c.1036C>A p.L346M | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55588990; called by muse, mutect2, varscan2
- ANXA11 | c.482C>A p.P161H | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99627020; called by muse, mutect2, varscan2
- AOX1 | c.2780A>G p.Q927R | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101021880; called by muse, mutect2, varscan2
- AP2A2 | c.2087C>T p.A696V | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.075); catalogued as rs1461980949, COSV59960735; called by muse, mutect2
- AP2M1 | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV53048467; called by muse, mutect2, varscan2
- AP5Z1 | c.1025T>C p.F342S | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.241); catalogued as COSV100804077; called by muse, mutect2, varscan2
- APOD | c.310A>G p.K104E | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV100581107; called by muse, mutect2, varscan2
- APP | c.1666G>A p.E556K | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.132); catalogued as rs760615902, COSV60997213; called by muse, mutect2, varscan2
- APPL1 | c.460del p.R154Efs*6 | Frame Shift Del (DEL) | VAF 32/135 reads (24%) | catalogued as rs749401724; called by mutect2, varscan2
- AREG | c.539G>A p.R180Q | Missense Mutation (SNP) | VAF 90/364 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1441562209; called by muse, mutect2, varscan2
- ARHGAP25 | c.1096G>A p.A366T (on ENST00000409202 / NM_001007231.3; = p.A358T on NM_014882.3) | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.03); catalogued as COSV99771348; called by muse, mutect2, varscan2
- ARHGAP4 | c.2182del p.A728Rfs*38 | Frame Shift Del (DEL) | VAF 10/42 reads (24%) | catalogued as COSV61686136; called by mutect2, pindel
- ARHGAP9 | c.2081+1G>A p.X694_splice (on ENST00000393797 / NM_001319850.2; = p.X675_splice on NM_032496.4) | Splice Site (SNP) | VAF 19/111 reads (17%) | catalogued as COSV99953977; called by muse, mutect2, varscan2
- ARHGEF17 | c.5377C>T p.L1793F | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.437); catalogued as rs776806426, COSV99735309; called by muse, mutect2, varscan2
- ARHGEF2 | c.917G>A p.C306Y (on ENST00000361247 / NM_001162383.2; = p.C278Y on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.657); catalogued as COSV100560402; called by muse, mutect2, varscan2
- ARHGEF9 | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99491631; called by muse, mutect2, varscan2
- ARID1A | c.3977del p.P1326Rfs*155 | Frame Shift Del (DEL) | VAF 17/80 reads (21%) | catalogued as COSV61372705; called by mutect2, pindel, varscan2
- ARID1A | c.4846G>A p.A1616T | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.542); catalogued as COSV100251136; called by muse, mutect2, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 8/47 reads (17%) | catalogued as COSV61389445; called by mutect2, pindel, varscan2
- ARID1A | c.6545C>T p.A2182V | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100251138; called by muse, mutect2, varscan2
- ARID3A | c.1607C>T p.A536V | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99708338; called by muse, mutect2, varscan2
- ARPP19 | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.419); catalogued as rs1347787342, COSV99992905; called by muse, mutect2, varscan2
- ARRDC2 | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as COSV99716693; called by muse, mutect2, varscan2
- ART1 | c.575G>T p.R192L | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV51702897, COSV99167149; called by muse, mutect2, varscan2
- ARVCF | c.2333C>T p.A778V | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as COSV99258188; called by muse, mutect2, varscan2
- ASXL2 | c.140G>A p.R47K | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV99078366, COSV99710840; called by muse, mutect2, varscan2
- ATAD2 | c.539C>A p.T180N | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99784419; called by muse, mutect2, varscan2
- ATF7IP | c.1879G>T p.E627* | Nonsense Mutation (SNP) | VAF 15/82 reads (18%) | catalogued as COSV99661492; called by muse, mutect2, varscan2
- ATN1 | c.3005G>A p.R1002H | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100755749; called by muse, mutect2, varscan2
- ATRN | c.3786G>A p.W1262* | Nonsense Mutation (SNP) | VAF 15/85 reads (18%) | catalogued as COSV53527603; called by muse, mutect2, varscan2
- B3GALT5 | c.491A>C p.D164A | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.022); catalogued as COSV100563352; called by muse, mutect2, varscan2
- BACE2 | c.305del p.P102Rfs*25 | Frame Shift Del (DEL) | VAF 16/69 reads (23%) | catalogued as rs771098505; called by mutect2, pindel, varscan2
- BAK1 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV100645844; called by muse, mutect2, varscan2
- BCL9 | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV99324879; called by muse, mutect2, varscan2
- BEST4 | c.73_74insT p.R25Mfs*23 | Frame Shift Ins (INS) | VAF 13/52 reads (25%) | catalogued as COSV100944000; called by mutect2, pindel, varscan2
- BEX4 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs761698011, COSV101015355; called by muse, mutect2, varscan2
- BIN3 | c.338del p.K113Sfs*13 | Frame Shift Del (DEL) | VAF 13/71 reads (18%) | catalogued as rs776003776; called by mutect2, pindel, varscan2
- BPHL | c.413G>A p.W138* | Nonsense Mutation (SNP) | VAF 23/86 reads (27%) | catalogued as COSV100984465; called by muse, mutect2, varscan2
- BRD1 | c.3115G>A p.A1039T (on ENST00000216267 / NM_001349940.1; = p.A1170T on NM_001304808.3) | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53455253; called by muse, mutect2, varscan2
- BRD1 | c.2666G>A p.R889H (on ENST00000216267 / NM_001349940.1; = p.R1020H on NM_001304808.3) | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.613); catalogued as rs757367533, COSV53454810; called by muse, mutect2, varscan2
- BRD3 | c.71del p.P24Rfs*24 | Frame Shift Del (DEL) | VAF 14/49 reads (29%) | catalogued as rs763134487; called by mutect2, varscan2
- BRICD5 | c.415C>T p.R139W | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.636); catalogued as rs755255014, COSV57031527; called by muse, mutect2, varscan2
- BRINP2 | c.1445C>T p.P482L | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs143438287, COSV100838156; called by muse, mutect2, varscan2
- BRINP3 | c.1990A>G p.N664D | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.162); catalogued as COSV100818641; called by muse, mutect2, varscan2
- BRSK1 | c.1190G>A p.R397Q | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.775); catalogued as rs746105345, COSV100473877, COSV100473906; called by muse, mutect2, varscan2
- BTBD9 | c.769C>T p.R257* | Nonsense Mutation (SNP) | VAF 10/39 reads (26%) | catalogued as rs889986664, COSV58424985, COSV58428560; called by muse, mutect2, varscan2
- BZW1 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as rs867499216, COSV100729838; called by muse, mutect2, varscan2
- C12orf40 | c.1822T>A p.L608I | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.038); catalogued as COSV100209933; called by muse, mutect2
- C1QTNF1 | c.430C>A p.H144N | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.014); catalogued as COSV100189846; called by muse, mutect2, varscan2
- C1QTNF8 | c.728G>A p.G243D | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1332353332, COSV100116388; called by muse, mutect2, varscan2
- C1orf112 | c.304C>T p.H102Y | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99609615; called by muse, mutect2, varscan2
- C20orf96 | c.209C>T p.T70M (on ENST00000360321 / NM_153269.3; = p.T69M on NM_080571.1) | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs768337298, COSV64404544; called by muse, mutect2, varscan2
- C21orf91 | c.7G>T p.E3* | Nonsense Mutation (SNP) | VAF 20/103 reads (19%) | catalogued as COSV99515995; called by muse, mutect2, varscan2
- C3orf70 | c.181C>A p.L61I | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.978); catalogued as COSV100621196; called by muse, mutect2, varscan2
- C5orf38 | c.226del p.D76Mfs*5 | Frame Shift Del (DEL) | VAF 19/75 reads (25%) | catalogued as rs746245907, COSV57410849; called by mutect2, pindel, varscan2
- C6 | c.828dup p.S277Efs*15 | Frame Shift Ins (INS) | VAF 14/74 reads (19%) | catalogued as rs372345940; called by mutect2, varscan2
- C9orf43 | c.21C>A p.S7R | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV99928286; called by muse, mutect2, varscan2
- CA5A | c.223G>A p.V75I | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.048); catalogued as rs369651699, COSV59240712; called by muse, mutect2, varscan2
- CACNA1C | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.408); catalogued as rs755579963, COSV100217680, COSV59753819; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1H | c.4828A>G p.I1610V | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.118); catalogued as rs1000114902, COSV100671883; called by muse, mutect2
- CADPS | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV51892283, COSV99337318; called by muse, mutect2, varscan2
- CALCOCO1 | c.1438C>T p.R480C | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1030520322, COSV100017258; called by muse, mutect2, varscan2
- CAMSAP2 | c.226C>A p.L76I | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.145); catalogued as COSV52669347; called by muse, mutect2
- CAMSAP2 | c.3789del p.K1263Nfs*19 (on ENST00000236925 / NM_001297707.2; = p.K1252Nfs*19 on NM_203459.3) | Frame Shift Del (DEL) | VAF 8/39 reads (21%) | catalogued as rs770273913; called by mutect2, varscan2
- CAMTA2 | c.2737C>A p.L913I | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV52778708, COSV52779880; called by muse, mutect2, varscan2
- CANX | c.556A>G p.T186A | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as COSV99910383; called by muse, mutect2, varscan2
- CAP1 | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as COSV61224269; called by muse, mutect2, varscan2
- CAPRIN2 | c.2158G>A p.V720I | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.878); catalogued as rs1031788472, COSV51833681, COSV99195470; called by muse, mutect2, varscan2
- CARD11 | c.2102C>T p.A701V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.922); catalogued as COSV100829134; called by muse, mutect2, varscan2
- CATSPER1 | c.1654C>T p.R552W | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756955557, COSV100375836; called by muse, mutect2, varscan2
- CBLL1 | c.419del p.K140Rfs*52 | Frame Shift Del (DEL) | VAF 11/53 reads (21%) | catalogued as rs1256378164; called by mutect2, pindel, varscan2
- CBX3 | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.273); catalogued as rs776140361, COSV100522906; called by mutect2, varscan2
- CC2D1B | c.1979G>A p.R660H | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.38); catalogued as rs759148224, COSV52561621, COSV99429900; called by muse, mutect2, varscan2
- CCDC171 | c.931C>A p.L311I | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs142027816, COSV99900298; called by muse, mutect2, varscan2
- CCDC178 | c.874del p.M292Wfs*3 | Frame Shift Del (DEL) | VAF 32/148 reads (22%) | catalogued as rs535192849; called by mutect2, varscan2
- CCDC27 | c.1915del p.L639Cfs*8 | Frame Shift Del (DEL) | VAF 6/40 reads (15%) | catalogued as rs751021664; called by mutect2, pindel
- CCDC33 | c.956G>A p.R319H | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs950076220, COSV58351382; called by muse, varscan2
- CCDC40 | c.669G>T p.Q223H | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.094); catalogued as COSV99481611; called by muse, mutect2, varscan2
- CCDC62 | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs1294173099, COSV99456889; called by muse, mutect2, varscan2
- CCDC7 | c.2872A>C p.K958Q | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.995); catalogued as COSV100178045; called by muse, mutect2, varscan2
- CCDC8 | c.890del p.G297Efs*12 | Frame Shift Del (DEL) | VAF 11/61 reads (18%) | catalogued as rs1450099223; called by mutect2, pindel, varscan2
- CCDC80 | c.1658del p.K553Rfs*2 | Frame Shift Del (DEL) | VAF 38/222 reads (17%) | catalogued as rs1253078189; called by mutect2, varscan2
- CCDC88A | c.5254G>A p.E1752K (on ENST00000436346 / NM_001365480.1; = p.E1724K on NM_018084.5) | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.021); catalogued as COSV55068281, COSV99710190; called by muse, mutect2, varscan2
- CCL24 | c.233A>C p.K78T | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.324); catalogued as COSV99768793; called by muse, mutect2, varscan2
- CCT2 | c.1501C>T p.R501* | Nonsense Mutation (SNP) | VAF 24/82 reads (29%) | catalogued as COSV100167573; called by muse, mutect2, varscan2
- CD247 | c.414C>A p.H138Q (on ENST00000362089 / NM_198053.3; = p.H137Q on NM_000734.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV100758328; called by muse, mutect2
- CD248 | c.1238G>T p.S413I | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.037); catalogued as COSV100256548; called by muse, mutect2, varscan2
- CD93 | c.1433C>T p.S478F | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as COSV99849098; called by muse, mutect2, varscan2
- CDC14A | c.375del p.Y126Ifs*64 | Frame Shift Del (DEL) | VAF 23/138 reads (17%) | catalogued as rs773911500; called by mutect2, pindel, varscan2
- CDH26 | c.1502G>A p.R501Q | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.041); catalogued as rs748571321, COSV99722229; called by muse, mutect2, varscan2
- CDHR3 | c.820T>C p.Y274H | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100488198; called by muse, mutect2, varscan2
- CDK5RAP3 | c.1335G>T p.Q445H | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV100621134; called by muse, mutect2, varscan2
- CDS2 | c.1307G>T p.G436V | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100986096; called by muse, mutect2, varscan2
- CELSR2 | c.4157G>A p.R1386H | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753369355, COSV54771057; called by muse, mutect2, varscan2
- CENPB | c.1108G>A p.A370T | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.149); catalogued as rs1157325288, COSV100713378; called by muse, mutect2, varscan2
- CENPQ | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs367615344, COSV59920891; called by muse, mutect2, varscan2
- CEP164 | c.1151A>G p.Q384R | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as rs1321810359, COSV99633051; called by muse, mutect2, varscan2
- CFAP43 | c.3040-2A>G p.X1014_splice | Splice Site (SNP) | VAF 15/43 reads (35%) | catalogued as COSV99530597; called by muse, mutect2, varscan2
- CFAP58 | c.931G>A p.A311T | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.46); PolyPhen benign (0.028); catalogued as COSV100458859; called by muse, mutect2, varscan2
- CFAP65 | c.3598G>A p.D1200N | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.055); catalogued as COSV58561278; called by muse, mutect2, varscan2
- CHAT | c.1186G>A p.V396M | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as rs536359684, COSV100339822; called by muse, mutect2, varscan2
- CHCHD3 | c.453G>T p.R151S | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99365876; called by muse, mutect2, varscan2
- CHD1 | c.964T>C p.W322R | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99399340; called by muse, mutect2, varscan2
- CHD7 | c.3334A>G p.N1112D | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101418162; called by muse, mutect2, varscan2
- CHD7 | c.8980G>A p.E2994K | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.043); catalogued as COSV71116131; called by muse, mutect2, varscan2
- CHI3L1 | c.451A>G p.T151A | Missense Mutation (SNP) | VAF 27/173 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as COSV99703899; called by muse, mutect2, varscan2
- CHID1 | c.711G>C p.Q237H | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as COSV100059667; called by muse, mutect2, varscan2
- CHST8 | c.869G>A p.R290Q | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs777824048, COSV52860836; called by muse, mutect2, varscan2
- CHTF18 | c.1403C>A p.P468H | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.339); catalogued as COSV99135708; called by muse, mutect2, varscan2
- CLCNKB | c.1451C>T p.T484M | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374545641; called by muse, mutect2, varscan2
- CLIP3 | c.961G>A p.G321S | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV62112903; called by muse, mutect2, varscan2
- CLTB | c.628A>G p.K210E (on ENST00000310418 / NM_007097.5; = p.K192E on NM_001834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99220873; called by muse, mutect2, varscan2
- CLUH | c.1769G>A p.R590H (on ENST00000435359; = p.R628H on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.321); catalogued as rs745452744, COSV101425898, COSV70929300, COSV70929554; called by muse, mutect2, varscan2
- CLVS2 | c.632A>G p.Y211C | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.912); catalogued as COSV99252507; called by muse, mutect2, varscan2
- CMTR2 | c.1870C>T p.R624C | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.226); catalogued as rs368719534; called by muse, varscan2
- CNIH2 | c.145C>T p.R49W | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.586); catalogued as COSV100268377; called by muse, mutect2, varscan2
- CNNM1 | c.1756C>T p.R586W | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs748978527, COSV63200443; called by muse, mutect2, varscan2
- CNTNAP1 | c.2923G>A p.V975M | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.847); catalogued as rs764772808, COSV52850202; called by muse, mutect2, varscan2
- CNTNAP2 | c.2262G>T p.K754N | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100665030, COSV62257249; called by muse, mutect2, varscan2
- CNTNAP3 | c.2350C>T p.L784F | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.887); catalogued as rs765643846, COSV99904555; called by muse, mutect2, varscan2
- COG4 | c.2235G>T p.R745= | Splice Region (SNP) | VAF 26/84 reads (31%) | catalogued as COSV99850729; called by muse, mutect2, varscan2
- COL5A1 | c.1114G>A p.A372T | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs755289850, COSV65670003; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL5A1 | c.1507C>T p.R503C | Missense Mutation (SNP) | VAF 43/156 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs781485753, COSV65666385; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COPA | c.163C>T p.R55* | Nonsense Mutation (SNP) | VAF 30/201 reads (15%) | catalogued as COSV54099440; called by muse, mutect2, varscan2
- CPN1 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.011); catalogued as COSV100962594; called by muse, mutect2, varscan2
- CPNE4 | c.684C>T p.C228= | Splice Region (SNP) | VAF 17/66 reads (26%) | catalogued as COSV101456647, COSV70202405; called by muse, mutect2, varscan2
- CREB5 | c.35A>G p.Q12R (on ENST00000357727 / NM_182898.4; = p.Q5R on NM_004904.3) | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.901); catalogued as COSV100744454; called by muse, mutect2, varscan2
- CREBZF | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.97); catalogued as COSV99476195; called by muse, mutect2, varscan2
- CRISPLD2 | c.1273G>A p.A425T | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.769); catalogued as COSV99295552; called by muse, mutect2, varscan2
- CRYAB | c.208C>A p.L70M | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.204); catalogued as COSV99909807; called by muse, mutect2, varscan2
- CRYBG2 | c.1178del p.K393Rfs*16 | Frame Shift Del (DEL) | VAF 14/57 reads (25%) | catalogued as rs747248693; called by mutect2, varscan2
- CSNK1G1 | c.1076G>A p.R359Q | Missense Mutation (SNP) | VAF 38/159 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.166); catalogued as rs957700531, COSV100274102; called by muse, mutect2, varscan2
- CSPP1 | c.2959G>A p.D987N (on ENST00000676605; = p.D946N on NM_024790.6) | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV99138333; called by muse, mutect2, varscan2
- CSRP3 | c.470C>T p.T157I | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99788208; called by muse, mutect2, varscan2
- CTCFL | c.1924G>A p.A642T | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs192956817, COSV99712455; called by muse, mutect2, varscan2
- CTSE | c.422C>T p.T141I | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100733603; called by muse, mutect2, varscan2
- CUL7 | c.4718G>A p.R1573Q | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.137); catalogued as rs780438062, COSV99538327; called by muse, mutect2, varscan2
- CUX2 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV99919306; called by muse, mutect2, varscan2
- CUX2 | c.3201G>T p.Q1067H | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99919309; called by muse, mutect2, varscan2
- CX3CR1 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV100843172; called by muse, mutect2, varscan2
- CXCL1 | c.86G>A p.G29D | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.255); catalogued as COSV101203924; called by muse, mutect2
- CXorf65 | c.508A>G p.N170D | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99340139; called by muse, mutect2, varscan2
- CYC1 | c.881T>C p.M294T | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV100010334; called by muse, mutect2, varscan2
- CYP27C1 | c.551C>T p.T184M | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749215631, COSV58867813; called by muse, mutect2, varscan2
- CYP2A6 | c.1026G>T p.K342N | Missense Mutation (SNP) | VAF 29/164 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.03); catalogued as COSV99991788; called by muse, mutect2, varscan2
- CYP4F11 | c.1496G>A p.R499H | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.215); catalogued as rs1395944138, COSV99930791; called by muse, mutect2, varscan2
- CYP4V2 | c.1176del p.P393Lfs*22 | Frame Shift Del (DEL) | VAF 35/202 reads (17%) | catalogued as COSV66504805; called by mutect2, pindel, varscan2
- CYREN | c.421G>T p.E141* | Nonsense Mutation (SNP) | VAF 5/38 reads (13%) | catalogued as COSV99313157; called by muse, mutect2, varscan2
- CYTL1 | c.94C>T p.R32W | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as rs773279143, COSV100312380; called by muse, mutect2, varscan2
- DAO | c.791G>A p.C264Y | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.325); catalogued as COSV99948526; called by muse, mutect2, varscan2
- DBNDD2 | c.590A>G p.E197G | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV100619533; called by muse, mutect2, varscan2
- DCAF12 | c.316G>T p.G106C | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100778366; called by muse, mutect2, varscan2
- DCAF4 | c.473del p.K158Rfs*32 | Frame Shift Del (DEL) | VAF 20/130 reads (15%) | catalogued as COSV62319096; called by mutect2, pindel, varscan2
- DCAF4L1 | c.1058C>A p.P353H | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100295657; called by muse, mutect2, varscan2
- DCBLD2 | c.1799G>A p.S600N | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.852); catalogued as COSV99504726; called by muse, mutect2, varscan2
- DCTN1 | c.1562G>A p.R521H | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs750997137, COSV62620808; called by muse, mutect2, varscan2
- DDOST | c.943C>T p.R315W (on ENST00000415136; = p.R298W on NM_005216.5) | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs142402976; called by muse, mutect2, varscan2
- DDR2 | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.375); catalogued as rs767283136, COSV63370128; called by muse, mutect2
- DDX53 | c.1067T>C p.L356P | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100028862; called by muse, mutect2, varscan2
- DENND4B | c.2222G>A p.R741H | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1470438978, COSV63409792; called by muse, mutect2, varscan2
- DGKA | c.2176del p.R726Afs*9 | Frame Shift Del (DEL) | VAF 17/74 reads (23%) | catalogued as COSV59384233; called by mutect2, pindel, varscan2
- DGKD | c.693G>T p.G231= (on ENST00000264057 / NM_152879.3; = p.G187= on NM_003648.3 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 8/37 reads (22%) | catalogued as COSV99896017; called by muse, mutect2, varscan2
- DGKH | c.411G>A p.M137I | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99818597; called by muse, mutect2, varscan2
- DICER1 | c.1505A>G p.E502G | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100601978; called by muse, mutect2, varscan2
- DIP2B | c.3257C>T p.A1086V | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV99998289; called by muse, mutect2, varscan2
- DISC1 | c.202C>A p.P68T | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.083); catalogued as COSV99697561; called by muse, mutect2, varscan2
- DNA2 | c.424C>A p.L142M | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100622497; called by muse, mutect2, varscan2
- DNAH10 | c.4445A>G p.Q1482R (on ENST00000409039; = p.Q1421R on NM_207437.3) | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as rs1321079751, COSV101292164; called by muse, mutect2, varscan2
- DNAH3 | c.8450G>A p.S2817N | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as COSV99766414; called by muse, varscan2
- DNAH5 | c.2624T>C p.L875S | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0.045); catalogued as COSV99448118; called by muse, mutect2, varscan2
- DNAH9 | c.647C>T p.A216V | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.904); catalogued as COSV99305248; called by muse, mutect2, varscan2
- DNAJB2 | c.94C>A p.P32T | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100338904, COSV60677766; called by muse, mutect2, varscan2
- DNASE1L1 | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs782331239, COSV99185884; called by muse, mutect2, varscan2
- DNM1 | c.1982C>T p.T661I | Missense Mutation (SNP) | VAF 62/240 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV57850780; called by muse, mutect2, varscan2
- DNM3 | c.1171G>A p.A391T | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV100798010; called by muse, mutect2, varscan2
- DNMT3A | c.1025A>G p.E342G | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.134); catalogued as COSV99261577; called by muse, mutect2, varscan2
- DOCK4 | c.1832A>G p.E611G | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101447832; called by muse, mutect2, varscan2
- DOCK5 | c.2312G>A p.R771Q | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs201426822, COSV99376645; called by muse, mutect2, varscan2
- DOK3 | c.913G>A p.G305R | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs371667577; called by muse, varscan2
- DOK4 | c.88G>T p.V30L | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); catalogued as COSV99538281; called by muse, mutect2, varscan2
- DOP1A | c.7348del p.I2450* | Frame Shift Del (DEL) | VAF 9/30 reads (30%) | catalogued as rs1562402608; called by mutect2, pindel, varscan2
- DOT1L | c.2740C>T p.L914F | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.997); catalogued as COSV101288604; called by muse, mutect2, varscan2
- DPAGT1 | c.1187C>A p.S396Y | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as COSV99597908; called by muse, mutect2, varscan2
- DSC2 | c.385G>A p.V129I | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as rs1283460190, COSV99199594; called by muse, mutect2, varscan2
- DSP | c.1388T>C p.L463P | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101131231; called by muse, mutect2, varscan2
- DTNA | c.1462C>T p.Q488* | Nonsense Mutation (SNP) | VAF 4/23 reads (17%) | catalogued as rs997041007, COSV99312054; called by muse, mutect2
- DUOX1 | c.1163T>A p.M388K | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100367856; called by muse, mutect2, varscan2
- DUS3L | c.233A>T p.E78V | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV100288085; called by muse, mutect2, varscan2
- DYNLL2 | c.30C>A p.N10K | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.644); catalogued as COSV101651059; called by muse, mutect2, varscan2
- DZANK1 | c.34A>G p.I12V | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.493); catalogued as rs373354864; called by muse, mutect2, varscan2
- E2F1 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs864622017, COSV58534885; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EARS2 | c.1069C>T p.L357= | Splice Region (SNP) | VAF 10/37 reads (27%) | catalogued as rs1567379536, COSV101492161; called by muse, mutect2
- EBF1 | c.1148C>T p.A383V | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as rs1206083268, COSV100565605; called by muse, varscan2
- ECHDC3 | c.500G>A p.S167N | Missense Mutation (SNP) | VAF 41/175 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV101004538; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs199901698, COSV62567512; called by muse, mutect2, varscan2
- EGR1 | c.518C>T p.S173L | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.202); catalogued as COSV99525390; called by muse, mutect2, varscan2
- EIF1AX | c.210G>T p.W70C | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63309369; called by muse, mutect2, varscan2
- EIF3J | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as COSV99970658; called by muse, mutect2, varscan2
- ELAC2 | c.1916C>T p.T639I | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99310485; called by muse, mutect2
- EMILIN1 | c.1525G>T p.G509W | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99565988; called by muse, mutect2
- EMILIN2 | c.1289T>C p.L430P | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs1298625877, COSV99598395; called by muse, mutect2, varscan2
- EOLA2 | c.158G>A p.C53Y | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV100778047; called by muse, mutect2, varscan2
- EPB41L3 | c.3188A>C p.Q1063P | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100548686; called by muse, mutect2, varscan2
- EPHB1 | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 31/182 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.207); catalogued as rs563780078, COSV67654835, COSV67657144; called by muse, mutect2, varscan2
- EPHX1 | c.293G>T p.R98L | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.123); catalogued as CM151151, COSV55300575; called by muse, mutect2, varscan2
- ERAP1 | c.1614G>T p.R538S | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV99700839; called by muse, mutect2, varscan2
- ERBB3 | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 71/214 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.341); catalogued as rs1324972550, COSV57259152; called by muse, mutect2, varscan2
- ERCC1 | c.515A>G p.Q172R | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99185261; called by muse, mutect2
- ERICH3 | c.761G>C p.R254T | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100443961; called by muse, mutect2, varscan2
- ESRP2 | c.1060C>T p.R354W (on ENST00000565858 / NM_001365264.1; = p.R344W on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs755162828, COSV99251226; called by muse, mutect2, varscan2
- ESYT1 | c.3140T>C p.L1047P | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.688); catalogued as COSV99919889; called by muse, mutect2, varscan2
- EYA2 | c.1570G>A p.A524T | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); catalogued as rs746552793, COSV100426681; called by muse, mutect2, varscan2
- FAF1 | c.14T>C p.M5T | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs768961921, COSV99395816; called by muse, mutect2, varscan2
- FAM114A1 | c.350C>A p.A117D | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV100729255; called by muse, mutect2, varscan2
- FAM160A2 | c.2386C>A p.L796M (on ENST00000449352 / NM_001098794.2; = p.L810M on NM_032127.4) | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99791938; called by muse, mutect2, varscan2
- FAM167A | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs758382682, COSV52668399; called by muse, mutect2, varscan2
- FAM174A | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.049); catalogued as COSV100444365; called by muse, mutect2, varscan2
- FAM174A | c.385A>C p.M129L | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.09); catalogued as COSV100444366; called by muse, mutect2, varscan2
- FAM186B | c.2606del p.K869Rfs*11 | Frame Shift Del (DEL) | VAF 42/112 reads (38%) | catalogued as rs768823856; called by mutect2, pindel, varscan2
- FAM78A | c.821C>A p.P274Q | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV99908490; called by muse, mutect2, varscan2
- FAM83E | c.303G>A p.W101* | Nonsense Mutation (SNP) | VAF 14/51 reads (27%) | catalogued as rs1203397814, COSV99320196; called by muse, mutect2, varscan2
- FANCB | c.2495G>T p.G832V | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.629); catalogued as COSV100146485; called by mutect2, varscan2
- FBN3 | c.5765C>T p.A1922V | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.055); catalogued as COSV99560576; called by muse, mutect2, varscan2
- FCGBP | c.7697G>A p.R2566H | Missense Mutation (SNP) | VAF 50/662 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs774365122; called by muse, mutect2
- FCGBP | c.1883C>T p.A628V | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as rs1375191294; called by muse, mutect2, varscan2
- FCN2 | c.509T>C p.L170P | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV99391216; called by muse, mutect2, varscan2
- FCRLB | c.1105C>T p.P369S | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.009); catalogued as COSV100396144; called by muse, mutect2, varscan2
- FGA | c.703G>A p.G235R | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs771102964, COSV57400935; called by muse, mutect2, varscan2
- FGD3 | c.1220G>A p.R407Q | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.701); catalogued as rs760017502, COSV100490507; called by muse, mutect2, varscan2
- FGD4 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.01); catalogued as COSV99846967; called by muse, mutect2, varscan2
- FGFR2 | c.549del p.N184Tfs*9 | Frame Shift Del (DEL) | VAF 30/133 reads (23%) | catalogued as rs1164513666; called by mutect2, pindel, varscan2
- FKBP9 | c.384dup p.N129Qfs*7 | Frame Shift Ins (INS) | VAF 33/161 reads (20%) | catalogued as rs752076602; called by mutect2, varscan2
- FLRT1 | c.958C>A p.L320M | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55359372; called by muse, mutect2, varscan2
- FMNL1 | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1235140964, COSV100056381; called by muse, mutect2, varscan2
- FNDC3A | c.1654A>T p.S552C (on ENST00000492622 / NM_001079673.2; = p.S496C on NM_014923.5) | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101256677; called by muse, mutect2, varscan2
- FNIP2 | c.2122C>A p.L708I | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0.104); catalogued as COSV100032476; called by muse, mutect2, varscan2
- FOXA1 | c.164C>T p.T55M | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.063); catalogued as rs1019690230, COSV99163324; called by muse, mutect2, varscan2
- FRMD3 | c.1688G>A p.R563H | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs779982501, COSV58462877; called by muse, mutect2, varscan2
- FSCB | c.97A>G p.N33D | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.964); catalogued as COSV100469165, COSV61219926; called by muse, mutect2, varscan2
- FUT1 | c.939G>T p.W313C | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59569650; called by muse, mutect2, varscan2
- FXR1 | c.371del p.N124Ifs*14 | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | catalogued as rs756304971; called by mutect2, varscan2
- GABBR2 | c.1681A>C p.T561P | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.825); catalogued as COSV99409739, COSV99410004; called by muse, mutect2, varscan2
- GAPDH | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 14/66 reads (21%) | catalogued as rs755829002, COSV99975468; called by muse, mutect2, varscan2
- GARS1 | c.1156T>C p.S386P | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as COSV101220060; called by muse, mutect2, varscan2
- GATA3 | c.641C>T p.S214L | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.028); catalogued as COSV100650939; called by muse, mutect2, varscan2
- GBF1 | c.4061A>G p.D1354G (on ENST00000369983 / NM_001377137.1; = p.D1353G on NM_004193.3) | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.179); catalogued as COSV100890429; called by muse, mutect2, varscan2
- GBP1 | c.1079G>A p.S360N | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV100976248; called by muse, mutect2, varscan2
- GDAP1 | c.330G>A p.M110I | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99619494; called by muse, mutect2, varscan2
- GDF6 | c.178G>A p.A60T | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV99747917; called by muse, mutect2
- GEMIN5 | c.967C>A p.L323I | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.114); catalogued as COSV53563567, COSV99593801; called by muse, mutect2, varscan2
- GEMIN6 | c.437G>A p.S146N | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99931570; called by muse, mutect2, varscan2
- GFRA1 | c.515C>T p.S172L | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747819350, COSV62602247; called by muse, mutect2, varscan2
- GJB1 | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs201697702, COSV100661228; ClinVar: benign; called by muse, mutect2, varscan2
- GLIPR2 | c.445G>A p.V149I | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1046499773, COSV100936994, COSV65029376; called by muse, mutect2, varscan2
- GLUD2 | c.295C>T p.R99W | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV100046721; called by muse, mutect2, varscan2
- GOLGA6A | c.650A>G p.Q217R | Missense Mutation (SNP) | VAF 42/574 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.607); catalogued as COSV99296930; called by muse, mutect2
- GOLT1A | c.221del p.G74Vfs*64 | Frame Shift Del (DEL) | VAF 7/63 reads (11%) | catalogued as rs765260894; called by mutect2, pindel, varscan2
- GPR141 | c.882G>T p.K294N | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.071); catalogued as COSV57731196, COSV57733250; called by muse, mutect2, varscan2
- GPR158 | c.3532A>G p.T1178A | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV100893251; called by muse, mutect2, varscan2
- GPR182 | c.29G>A p.G10D | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.037); catalogued as COSV100267687; called by muse, mutect2, varscan2
- GPR63 | c.623G>A p.C208Y | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.639); catalogued as rs1272584030, COSV100013263; called by muse, mutect2, varscan2
- GPRC6A | c.1912C>G p.L638V | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.047); catalogued as COSV100114248, COSV59952582; called by muse, mutect2, varscan2
- GRAMD1B | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs375511617; called by muse, mutect2, varscan2
- GRAMD1C | c.1526T>C p.L509P | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV100822856; called by muse, mutect2, varscan2
- GRAP2 | c.136G>A p.V46M | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100702938; called by muse, mutect2, varscan2
- GRB7 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV100485449; called by muse, mutect2, varscan2
- GRIN2D | c.2303G>A p.R768H | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.789); catalogued as rs772617040, COSV99474330; called by muse, mutect2, varscan2
- GUCY2C | c.3206A>G p.E1069G | Missense Mutation (SNP) | VAF 66/174 reads (38%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.021); catalogued as COSV99663491; called by muse, mutect2, varscan2
- GUCY2F | c.2821C>A p.L941I | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV54307820; called by muse, mutect2, varscan2
- GUF1 | c.1934del p.K645Sfs*2 | Frame Shift Del (DEL) | VAF 10/50 reads (20%) | catalogued as COSV54945907; called by mutect2, varscan2
- H6PD | c.2324C>T p.P775L | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.369); catalogued as rs145080671; called by muse, mutect2, varscan2
- HAAO | c.106T>C p.F36L | Missense Mutation (SNP) | VAF 54/218 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV99685335; called by muse, mutect2
- HACD4 | c.689del p.K230Rfs*45 | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | catalogued as rs768797944; called by mutect2, varscan2
- HAUS5 | c.719del p.P240Qfs*73 | Frame Shift Del (DEL) | VAF 15/66 reads (23%) | catalogued as rs1169026761; called by mutect2, pindel, varscan2
- HAUS6 | c.1588del p.S530Vfs*12 | Frame Shift Del (DEL) | VAF 28/106 reads (26%) | catalogued as rs34558496; called by mutect2, pindel, varscan2
- HBP1 | c.869G>T p.G290V | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.272); catalogued as COSV99753161; called by muse, varscan2
- HCAR2 | c.113T>G p.F38C | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); catalogued as COSV100186469, COSV100186547; called by muse, mutect2, varscan2
- HCFC1R1 | c.249del p.M84* | Frame Shift Del (DEL) | VAF 11/31 reads (35%) | catalogued as rs746547303; called by mutect2, pindel, varscan2
- HDLBP | c.1034G>T p.G345V | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100190305; called by muse, mutect2, varscan2
- HECA | c.1004del p.G335Dfs*27 | Frame Shift Del (DEL) | VAF 10/82 reads (12%) | catalogued as rs771658394; called by mutect2, pindel, varscan2
- HERC2 | c.8336T>G p.L2779R | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.548); catalogued as COSV99872601; called by muse, mutect2, varscan2
- HGFAC | c.1800del p.L602Wfs*70 | Frame Shift Del (DEL) | VAF 25/157 reads (16%) | catalogued as rs770643102; called by pindel, varscan2
- HGFAC | c.1802C>A p.P601H | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101237790; called by muse, varscan2
- HGS | c.510G>T p.R170S | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100230400; called by muse, mutect2, varscan2
- HMCN1 | c.1408C>T p.L470F | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs747920607, COSV54888732; called by muse, mutect2, varscan2
- HMGCS1 | c.830G>A p.R277Q | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57292163; called by muse, mutect2, varscan2
- HOMEZ | c.439C>T p.R147W | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.987); catalogued as rs750934524, COSV62537447; called by muse, mutect2, varscan2
- HOXA3 | c.903_904insA p.Q302Tfs*42 | Frame Shift Ins (INS) | VAF 6/18 reads (33%) | catalogued as COSV100415407; called by mutect2, varscan2
- HSP90AA1 | c.910A>G p.I304V | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.73); catalogued as COSV99355186; called by muse, mutect2, varscan2
- HSPH1 | c.1986T>G p.H662Q | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as COSV100184839; called by muse, mutect2, varscan2
- IFNGR2 | c.170G>A p.S57N | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV99274632; called by muse, mutect2, varscan2
- IFRD2 | c.919G>A p.A307T | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.666); catalogued as rs1394765711, COSV100269422; called by muse, mutect2, varscan2
- IFT140 | c.4298G>T p.R1433L | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as COSV99248205; called by muse, mutect2, varscan2
- IFT57 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV99197368; called by muse, mutect2, varscan2
- IGF2BP1 | c.682A>G p.K228E | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.689); catalogued as COSV51730332; called by muse, mutect2, varscan2
- IGHM | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (1); PolyPhen possibly damaging (0.691); catalogued as rs782402963; called by muse, mutect2, varscan2
- IGSF10 | c.4175C>T p.A1392V | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV99178549; called by muse, mutect2, varscan2
- IGSF5 | c.277T>A p.F93I | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.372); catalogued as COSV101012035; called by muse, mutect2, varscan2
- IKBKE | c.230G>A p.G77D | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.834); catalogued as COSV100898190; called by muse, mutect2, varscan2
- IL17B | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs748708206, COSV99199171; called by muse, mutect2, varscan2
- IL22RA2 | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761897135, COSV99760635; called by muse, mutect2, varscan2
- IL4I1 | c.434C>T p.T145M | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs776097662, COSV100351930; called by muse, mutect2, varscan2
- INO80 | c.1373C>A p.A458D | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100731745; called by muse, mutect2, varscan2
- INO80C | c.284G>T p.G95V | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV99358483; called by muse, mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 15/55 reads (27%) | catalogued as rs760925109; called by mutect2, pindel, varscan2
- INTS1 | c.3467G>A p.S1156N | Missense Mutation (SNP) | VAF 34/200 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as COSV101247802; called by muse, mutect2, varscan2
- INTS14 | c.1256T>C p.I419T (on ENST00000313182 / NM_001366360.2; = p.I340T on NM_001136043.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV99971004; called by muse, varscan2
- INTS6L | c.359del p.L120* | Frame Shift Del (DEL) | VAF 26/105 reads (25%) | catalogued as rs782242788; ClinVar: uncertain significance; called by mutect2, varscan2
- IQCJ-SCHIP1 | c.307G>T p.G103W (on ENST00000485419 / NM_001197113.1; = p.G27W on NM_014575.3) | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100540410; called by muse, mutect2, varscan2
- IRF4 | c.431C>A p.P144Q | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV101110823; called by muse, mutect2, varscan2
- IRS1 | c.989G>A p.S330N | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100524338; called by muse, mutect2, varscan2
- ITIH6 | c.3188T>C p.V1063A | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99513145; called by muse, mutect2
- ITLN1 | c.505T>C p.Y169H | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58277163; called by muse, mutect2, varscan2
- ITPKC | c.1467C>T p.S489= | Splice Region (SNP) | VAF 13/44 reads (30%) | catalogued as rs749864734, COSV99648632; called by muse, mutect2
- KALRN | c.1370A>G p.H457R | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); catalogued as COSV99563440; called by muse, mutect2, varscan2
- KBTBD2 | c.123A>T p.E41D | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.983); catalogued as COSV100406456; called by muse, mutect2, varscan2
- KCNA2 | c.1130A>G p.Y377C | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100315908; called by muse, mutect2, varscan2
- KCNH7 | c.2977C>T p.R993* | Nonsense Mutation (SNP) | VAF 12/54 reads (22%) | catalogued as COSV59794929; called by muse, mutect2, varscan2
- KCNJ13 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 18/58 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV99289288; called by muse, mutect2, varscan2
- KCNK16 | c.22A>G p.S8G | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV100949164; called by muse, mutect2, varscan2
- KDF1 | c.1099C>T p.P367S | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.654); catalogued as COSV100264442; called by muse, mutect2, varscan2
- KDM3B | c.2541del p.N848Mfs*28 | Frame Shift Del (DEL) | VAF 9/32 reads (28%) | catalogued as COSV58689436; called by mutect2, pindel, varscan2
- KIAA0753 | c.428G>T p.R143M | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.639); catalogued as COSV100810566; called by muse, mutect2, varscan2
- KIAA1109 | c.665C>T p.T222I | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99151551; called by muse, mutect2, varscan2
- KIAA1549L | c.1466C>A p.P489H (on ENST00000321505; = p.P786H on NM_012194.3) | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.533); catalogued as COSV55778401; called by muse, mutect2, varscan2
- KIF14 | c.2048G>A p.S683N | Missense Mutation (SNP) | VAF 23/179 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV100950785; called by muse, mutect2, varscan2
- KIF26B | c.2668G>A p.V890I | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.458); catalogued as COSV100832079; called by muse, mutect2, varscan2
- KIF4A | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.486); catalogued as COSV100979475; called by muse, mutect2, varscan2
- KIT | c.2866C>T p.R956W | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587778433, COSV55390509; ClinVar: uncertain significance / not provided; called by muse, mutect2, varscan2
- KLF13 | c.595T>C p.C199R | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100207100; called by muse, mutect2
- KLF15 | c.631C>A p.P211T | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV99955128; called by muse, mutect2, varscan2
- KLHDC4 | c.708G>A p.M236I | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.74); catalogued as COSV99566311; called by muse, mutect2, varscan2
- KLHL21 | c.1003A>G p.N335D | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as COSV100887218; called by muse, mutect2, varscan2
- KLK15 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as rs758236941, COSV56826659; called by muse, mutect2, varscan2
- KMT2D | c.2506del p.Q836Sfs*94 | Frame Shift Del (DEL) | VAF 15/124 reads (12%) | catalogued as COSV56411048; called by mutect2, pindel, varscan2
- KNDC1 | c.3590C>T p.A1197V | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.325); catalogued as rs545314975, COSV100464303; called by muse, mutect2, varscan2
- KNL1 | c.6311T>C p.V2104A (on ENST00000346991 / NM_170589.5; = p.V2078A on NM_144508.5) | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as COSV61158058; called by muse, mutect2, varscan2
- KPNA6 | c.1094C>T p.A365V | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV101012467; called by mutect2, varscan2
- KRT32 | c.867G>A p.M289I | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as rs776314677, COSV99862971; called by muse, mutect2, varscan2
- KRT73 | c.73T>A p.S25T | Missense Mutation (SNP) | VAF 27/221 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99988424; called by muse, mutect2, varscan2
- KSR2 | c.787C>T p.R263C | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.619); catalogued as rs748664847, COSV60372983; called by muse, varscan2
- KTN1 | c.1969C>A p.L657M | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV101255133; called by muse, mutect2, varscan2
- L2HGDH | c.1169C>T p.P390L | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99910218; called by muse, mutect2, varscan2
- LAD1 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.046); catalogued as COSV100943822; called by muse, mutect2, varscan2
- LAMA4 | c.2781G>A p.W927* (on ENST00000230538 / NM_001105206.3; = p.W920* on NM_002290.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 12/79 reads (15%) | catalogued as COSV100038128; called by muse, mutect2, varscan2
- LAMA4 | c.1144A>C p.S382R (on ENST00000230538 / NM_001105206.3; = p.S375R on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.038); catalogued as COSV100038131; called by muse, mutect2, varscan2
- LAMB4 | c.26del p.L9Cfs*43 | Frame Shift Del (DEL) | VAF 8/44 reads (18%) | catalogued as rs747409331; called by mutect2, pindel, varscan2
- LAMC1 | c.2647+2T>C p.X883_splice | Splice Site (SNP) | VAF 6/51 reads (12%) | catalogued as COSV99279373; called by muse, mutect2
- LANCL3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs1569459785, COSV101065574; called by muse, mutect2, varscan2
- LAPTM4A | c.525del p.F175Lfs*5 | Frame Shift Del (DEL) | VAF 11/67 reads (16%) | catalogued as rs1476796878; called by mutect2, pindel, varscan2
- LARS1 | c.2422del p.T808Qfs*8 (on ENST00000394434 / NM_020117.11; = p.T781Qfs*8 on NM_016460.3) | Frame Shift Del (DEL) | VAF 13/78 reads (17%) | catalogued as COSV50975244; called by mutect2, pindel, varscan2
- LATS1 | c.1979G>A p.R660H | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99485703; called by muse, mutect2, varscan2
- LCOR | c.2328G>T p.E776D | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.341); catalogued as COSV99616670; called by muse, mutect2
- LCT | c.3656C>A p.P1219H | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV99929148; called by muse, mutect2, varscan2
- LIG1 | c.2111T>C p.I704T | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99618770; called by muse, mutect2, varscan2
- LILRA2 | c.1013A>G p.K338R | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as COSV99253175; called by muse, mutect2, varscan2
- LILRB1 | c.1600C>T p.R534* (on ENST00000427581; = p.R484* on NM_006669.6) | Nonsense Mutation (SNP) | VAF 28/105 reads (27%) | catalogued as rs376266152; called by muse, mutect2, varscan2
- LMTK2 | c.3019G>A p.E1007K | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.225); catalogued as rs184715893, COSV51994512; called by muse, mutect2, varscan2
- LNPK | c.104del p.N35Ifs*12 | Frame Shift Del (DEL) | VAF 18/72 reads (25%) | catalogued as rs1443101323; called by mutect2, pindel, varscan2
- LRCH4 | c.1940del p.G647Afs*103 | Frame Shift Del (DEL) | VAF 14/85 reads (16%) | catalogued as rs757069747; called by mutect2, pindel, varscan2
- LRP1B | c.1362G>T p.E454D | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101257727, COSV67248819; called by muse, mutect2, varscan2
- LRRC3 | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1175165323, COSV52400444; called by muse, mutect2, varscan2
- LRRC45 | c.1561G>T p.G521C | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.174); catalogued as COSV100141777; called by muse, mutect2
- LRRIQ4 | c.247C>A p.L83M | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); catalogued as COSV100540187; called by muse, mutect2, varscan2
- LRRK1 | c.3828dup p.F1277Ifs*6 | Frame Shift Ins (INS) | VAF 33/159 reads (21%) | catalogued as rs778455063; called by mutect2, pindel, varscan2
- LSM10 | c.362dup p.N121Kfs*3 | Frame Shift Ins (INS) | VAF 13/89 reads (15%) | catalogued as rs768776995; called by mutect2, pindel, varscan2
- LTBP2 | c.5020del p.A1674Pfs*67 | Frame Shift Del (DEL) | VAF 28/80 reads (35%) | catalogued as rs761199739; called by mutect2, varscan2
- LYSMD1 | c.539A>G p.E180G | Missense Mutation (SNP) | VAF 36/226 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.11); catalogued as COSV100925206; called by muse, mutect2, varscan2
- MACF1 | c.10957C>T p.Q3653* (on ENST00000372915; = p.Q1586* on NM_012090.5) | Nonsense Mutation (SNP) | VAF 10/43 reads (23%) | catalogued as COSV57139441, COSV99243314; called by muse, mutect2, varscan2
- MAGEA10 | c.497del p.R166Kfs*26 | Frame Shift Del (DEL) | VAF 12/82 reads (15%) | catalogued as COSV54882853; called by mutect2, pindel, varscan2
- MAGEA8 | c.607G>T p.G203C | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99674520; called by muse, mutect2, varscan2
- MAK | c.871G>T p.G291C | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100504353, COSV57564334; called by muse, mutect2, varscan2
- MAML2 | c.3248C>T p.T1083M | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.65); catalogued as rs370201127; called by muse, mutect2, varscan2
- MAP6 | c.1013C>T p.A338V | Missense Mutation (SNP) | VAF 48/214 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1222589103, COSV100496605; called by muse, mutect2, varscan2
- MARCHF4 | c.258del p.W87Gfs*72 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as rs1559109946; called by mutect2, pindel, varscan2
- MBD6 | c.2200del p.Q734Nfs*18 | Frame Shift Del (DEL) | VAF 19/73 reads (26%) | catalogued as rs749738168; called by mutect2, pindel, varscan2
- MDN1 | c.5966del p.K1989Rfs*65 | Frame Shift Del (DEL) | VAF 8/50 reads (16%) | catalogued as rs750092100; called by mutect2, varscan2
- MED12 | c.1562G>A p.R521H | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs875989806, COSV61337658; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MED28 | c.343G>A p.V115M | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as COSV99403686; called by muse, mutect2
- MEF2D | c.535C>A p.L179M | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV100559968, COSV61728469; called by muse, mutect2, varscan2
- MFGE8 | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1278108574, COSV99183949; called by muse, mutect2, varscan2
- MFSD11 | c.388C>A p.H130N | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV100333750; called by muse, mutect2, varscan2
- MICU2 | c.1043-1G>A p.X348_splice | Splice Site (SNP) | VAF 11/54 reads (20%) | catalogued as COSV101212428; called by muse, mutect2, varscan2
- MINAR1 | c.2104del p.S702Afs*11 | Frame Shift Del (DEL) | VAF 20/46 reads (43%) | catalogued as rs748072217, COSV59581461; called by mutect2, varscan2
- MIS18BP1 | c.1139del p.N380Ifs*3 | Frame Shift Del (DEL) | VAF 14/74 reads (19%) | catalogued as rs751180035; called by mutect2, varscan2
- MKS1 | c.1307C>A p.P436H | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99836403; called by muse, mutect2, varscan2
- MLF1 | c.760del p.D254Tfs*10 | Frame Shift Del (DEL) | VAF 16/100 reads (16%) | catalogued as COSV100575930, COSV63032654; called by mutect2, pindel, varscan2
- MRO | c.409A>G p.T137A | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as COSV56498177, COSV99839148; called by muse, varscan2
- MRPL37 | c.460G>A p.V154I | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.224); catalogued as rs375324336; called by muse, mutect2, varscan2
- MRTFB | c.2720G>A p.S907N (on ENST00000571589 / NM_001365412.2; = p.S857N on NM_014048.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100371095; called by muse, mutect2, varscan2
- MSC | c.325C>T p.R109W | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100335645; called by muse, mutect2
- MSI2 | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as rs200547992, COSV52361909; called by muse, mutect2, varscan2
- MTA1 | c.1833G>T p.Q611H | Missense Mutation (SNP) | VAF 38/175 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV100231619; called by muse, mutect2, varscan2
- MTHFD1 | c.2365G>A p.A789T | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV99386760; called by muse, mutect2
- MTMR4 | c.15del p.S8Afs*16 | Frame Shift Del (DEL) | VAF 8/47 reads (17%) | catalogued as COSV100051534; called by mutect2, pindel
- MTRF1L | c.1061A>G p.Y354C | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV100922442; called by muse, mutect2, varscan2
- MUC16 | c.40646C>T p.A13549V | Missense Mutation (SNP) | VAF 45/198 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.847); catalogued as COSV101109820; called by muse, mutect2, varscan2
- MUC16 | c.14486A>G p.N4829S | Missense Mutation (SNP) | VAF 62/252 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.445); catalogued as COSV101199351; called by muse, mutect2, varscan2
- MUC16 | c.10762G>A p.A3588T | Missense Mutation (SNP) | VAF 50/177 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.184); catalogued as COSV101199352; called by muse, mutect2, varscan2
- MUC17 | c.8750G>A p.S2917N | Missense Mutation (SNP) | VAF 45/173 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as COSV100072693; called by muse, mutect2, varscan2
- MUC4 | c.15088A>G p.R5030G (on ENST00000463781 / NM_018406.7; = p.R794G on NM_004532.6) | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV100204284; called by muse, mutect2, varscan2
- MUC4 | c.13242+2T>C p.X4414_splice (on ENST00000463781 / NM_018406.7; = p.X178_splice on NM_004532.6) | Splice Site (SNP) | VAF 19/80 reads (24%) | catalogued as COSV100204288; called by muse, mutect2, varscan2
- MYH1 | c.4445G>A p.S1482N | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.108); catalogued as COSV99875546; called by muse, mutect2, varscan2
- MYH14 | c.3815G>A p.R1272H | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.393); catalogued as rs572780596, COSV99222376; called by muse, mutect2, varscan2
- MYH14 | c.4351A>T p.M1451L | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV99222381; called by muse, mutect2
- MYH4 | c.5059G>A p.A1687T | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.033); catalogued as rs762780447, COSV99700974; called by muse, mutect2, varscan2
- MYO1A | c.520del p.L174Sfs*15 | Frame Shift Del (DEL) | VAF 20/111 reads (18%) | catalogued as COSV100270847; called by mutect2, pindel, varscan2
- MYO9B | c.2890C>T p.Q964* | Nonsense Mutation (SNP) | VAF 8/27 reads (30%) | catalogued as COSV101261486; called by muse, mutect2, varscan2
- NAB2 | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.063); catalogued as COSV100272630; called by muse, mutect2
- NARS1 | c.1152del p.K385Nfs*7 | Frame Shift Del (DEL) | VAF 8/23 reads (35%) | catalogued as rs1424147998, COSV99900593; called by mutect2, varscan2
- NCAM1 | c.1763C>T p.A588V (on ENST00000316851 / NM_181351.5; = p.A578V on NM_000615.7) | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57516657; called by muse, mutect2, varscan2
- NCLN | c.665T>C p.V222A | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.193); catalogued as COSV99859851; called by muse, mutect2, varscan2
- NCOR2 | c.4975C>A p.P1659T | Missense Mutation (SNP) | VAF 62/225 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100657157; called by muse, mutect2, varscan2
- NDUFA8 | c.52-1G>T p.X18_splice | Splice Site (SNP) | VAF 6/18 reads (33%) | catalogued as COSV101056791; called by muse, mutect2
- NEBL | c.1894C>T p.H632Y | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV101009164; called by muse, mutect2, varscan2
- NES | c.1176del p.T393Hfs*9 | Frame Shift Del (DEL) | VAF 12/88 reads (14%) | catalogued as rs759081520; called by mutect2, pindel, varscan2
- NEXMIF | c.761C>A p.S254Y | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as COSV50100848, COSV99280382; called by muse, mutect2, varscan2
- NFASC | c.2962A>G p.T988A | Missense Mutation (SNP) | VAF 22/182 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV58370914; called by muse, mutect2, varscan2
- NFX1 | c.2224+1G>A p.X742_splice | Splice Site (SNP) | VAF 6/37 reads (16%) | catalogued as COSV100582024; called by muse, mutect2, varscan2
- NINJ2 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.175); catalogued as rs749435320, COSV99842547; called by muse, mutect2, varscan2
- NIPBL | c.1513del p.R505Efs*35 | Frame Shift Del (DEL) | VAF 9/27 reads (33%) | catalogued as rs34314728; called by mutect2, varscan2
- NKAPL | c.194C>A p.P65H | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as COSV100642488; called by muse, mutect2, varscan2
- NMUR2 | c.481C>T p.R161C | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.567); catalogued as rs750095849, COSV99676648, COSV99676784; called by muse, mutect2, varscan2
- NOS3 | c.1319del p.G440Afs*64 | Frame Shift Del (DEL) | VAF 9/57 reads (16%) | catalogued as rs749517498, COSV52496454; called by mutect2, pindel, varscan2
- NOTCH4 | c.1906C>T p.P636S | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV100900597, COSV66679878; called by muse, mutect2, varscan2
- NOXA1 | c.1090C>T p.H364Y | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as COSV100395514; called by muse, mutect2, varscan2
- NPEPL1 | c.1331C>T p.A444V | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100622398; called by muse, mutect2, varscan2
- NPFFR1 | c.1288A>G p.I430V | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.017); catalogued as COSV99524771; called by muse, mutect2
- NPHS2 | c.442A>G p.K148E | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as COSV100858152; called by muse, mutect2, varscan2
- NPY5R | c.585G>C p.R195S | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as COSV100642740, COSV58452063; called by muse, mutect2, varscan2
- NRIP1 | c.2184del p.E729Rfs*5 | Frame Shift Del (DEL) | VAF 8/44 reads (18%) | catalogued as rs776154715; called by mutect2, varscan2
- NRXN1 | c.3721C>T p.R1241C | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60485335; called by muse, mutect2
- NSD3 | c.3827G>A p.G1276E | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100395216; called by muse, mutect2, varscan2
- NT5C1A | c.622G>A p.V208M | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs142396494; called by muse, mutect2, varscan2
- NUDT17 | c.316G>A p.V106I | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV100492848; called by muse, mutect2, varscan2
- NUDT9 | c.890A>T p.N297I | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.235); catalogued as COSV100139187; called by muse, mutect2, varscan2
- NUP133 | c.1504A>G p.M502V | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs986051527, COSV99772649; called by muse, mutect2
- NUP153 | c.3710G>A p.S1237N | Missense Mutation (SNP) | VAF 4/61 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.598); catalogued as COSV50462379; called by muse, mutect2
- NUP210 | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201239438, COSV99595992; called by muse, mutect2, varscan2
- NUP98 | c.2248C>A p.L750I | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100262056; called by muse, mutect2, varscan2
- OGDH | c.240del p.R81Afs*19 | Frame Shift Del (DEL) | VAF 24/116 reads (21%) | catalogued as rs777887578; called by mutect2, varscan2
- OGDH | c.2023G>A p.G675S | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56056835; called by muse, mutect2, varscan2
- OLFML2B | c.2216G>A p.G739D | Missense Mutation (SNP) | VAF 38/223 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99668289; called by muse, mutect2, varscan2
- OR2T6 | c.697G>T p.G233W | Missense Mutation (SNP) | VAF 40/286 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100861528; called by muse, mutect2
- OR5B12 | c.597del p.F199Lfs*13 | Frame Shift Del (DEL) | VAF 7/45 reads (16%) | catalogued as rs747074822; called by mutect2, varscan2
- OR6C6 | c.802G>A p.V268I | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); catalogued as COSV100626450; called by muse, mutect2, varscan2
- OR8A1 | c.734C>T p.A245V | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0.02); catalogued as COSV99420496; called by muse, mutect2, varscan2
- OR9K2 | c.978del p.K326Nfs*3 (on ENST00000305377; = p.K304Nfs*3 on NM_001005243.1) | Frame Shift Del (DEL) | VAF 12/68 reads (18%) | catalogued as rs1249976011; called by mutect2, pindel, varscan2
- OSBPL1A | c.2378del p.N793Mfs*15 (on ENST00000319481 / NM_080597.4; = p.N280Mfs*15 on NM_018030.4) | Frame Shift Del (DEL) | VAF 25/120 reads (21%) | catalogued as rs751106039; called by mutect2, varscan2
- OSGEPL1 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV99918349; called by muse, mutect2, varscan2
- OTOP2 | c.260G>T p.C87F | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.178); catalogued as rs764744021, COSV100140401; called by muse, mutect2, varscan2
- OTP | c.178G>A p.G60R | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs750666826, COSV100119758; called by muse, mutect2, varscan2
- OTUD4 | c.3120G>T p.K1040N (on ENST00000447906 / NM_001366057.1; = p.K975N on NM_001102653.1) | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101485947; called by muse, mutect2, varscan2
- OXR1 | c.1205C>T p.S402F (on ENST00000442977 / NM_001198532.1; = p.S401F on NM_018002.3) | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as COSV100367138; called by muse, mutect2, varscan2
- P2RY4 | c.62G>A p.S21N | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100997003; called by muse, mutect2, varscan2
- PADI1 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.431); catalogued as rs200141204, COSV64937802; called by muse, mutect2, varscan2
- PAGE1 | c.141G>T p.E47D | Missense Mutation (SNP) | VAF 69/298 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.289); catalogued as COSV65998434; called by muse, varscan2
- PAPPA2 | c.1559G>A p.R520Q | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.255); catalogued as rs762087707, COSV100867333, COSV62773745, COSV62780042; called by muse, mutect2, varscan2
- PARD6G | c.820G>A p.A274T | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs753393239, COSV100783378; called by muse, varscan2
- PAXX | c.280G>T p.A94S | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as COSV100860377; called by muse, mutect2
- PBX2 | c.440G>A p.G147D | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as rs1215997681, COSV100903992; called by muse, mutect2, varscan2
- PCDHB4 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.087); catalogued as COSV52023242; called by muse, mutect2, varscan2
- PCDHGB5 | c.1535C>T p.A512V | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs759226157, COSV54018960; called by muse, mutect2, varscan2
- PCED1A | c.1269del p.C425Afs*11 | Frame Shift Del (DEL) | VAF 7/43 reads (16%) | catalogued as rs772305388; called by mutect2, pindel, varscan2
- PCNX2 | c.3308C>T p.A1103V | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV99266961; called by muse, mutect2, varscan2
- PCSK7 | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.091); catalogued as COSV58008706; called by muse, mutect2, varscan2
- PDE1A | c.824+2T>A p.X275_splice | Splice Site (SNP) | VAF 12/54 reads (22%) | catalogued as COSV100113824; called by muse, mutect2, varscan2
- PDGFRA | c.1471G>A p.A491T | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0.037); catalogued as rs563016888, COSV57265591, COSV99958005; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- PDPR | c.1175G>A p.G392D | Missense Mutation (SNP) | VAF 12/131 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV99848091; called by muse, mutect2, varscan2
- PDZD3 | c.557del p.P186Lfs*5 (on ENST00000531114; = p.P120Lfs*5 on NM_024791.4) | Frame Shift Del (DEL) | VAF 11/51 reads (22%) | catalogued as rs34614653; called by mutect2, pindel, varscan2
- PFKP | c.611C>T p.T204M | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775508957, COSV101127140; called by muse, mutect2, varscan2
- PGBD4 | c.1751del p.N584Ifs*21 | Frame Shift Del (DEL) | VAF 7/44 reads (16%) | catalogued as rs770560794; called by mutect2, varscan2
- PGBD5 | c.893G>A p.R298H (on ENST00000525115; = p.R367H on NM_001258311.2) | Missense Mutation (SNP) | VAF 28/169 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs771554152, COSV58413192; called by muse, mutect2, varscan2
- PGK1 | c.1130C>T p.A377V | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.983); catalogued as COSV100540633; called by muse, mutect2, varscan2
- PHF3 | c.3408del p.V1137* | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | catalogued as rs1163689977; called by mutect2, pindel, varscan2
- PHLPP1 | c.2713C>T p.R905C | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs780582578, COSV53038784; called by muse, mutect2, varscan2
- PIK3R6 | c.1379T>C p.V460A | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.171); catalogued as COSV100266355; called by muse, mutect2, varscan2
- PLA2G6 | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs138040351; called by muse, mutect2, varscan2
- PLA2R1 | c.176T>C p.L59P | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99322655; called by muse, mutect2, varscan2
- PLEKHG4B | c.106G>A p.A36T (on ENST00000283426; = p.A392T on NM_052909.5) | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV99360118; called by muse, mutect2, varscan2
- PLEKHO2 | c.409C>A p.L137M | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100060658; called by muse, mutect2, varscan2
- PLOD3 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 35/172 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as COSV99777943; called by muse, mutect2, varscan2
- PLPPR4 | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100926759; called by muse, mutect2, varscan2
- PLS3 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.025); catalogued as COSV99171629; called by muse, mutect2, varscan2
- PLXNA2 | c.3603C>A p.C1201* | Nonsense Mutation (SNP) | VAF 11/64 reads (17%) | catalogued as COSV100885326, COSV65444474; called by muse, mutect2, varscan2
- PLXNA2 | c.2608C>T p.P870S | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.173); catalogued as COSV100885327; called by muse, mutect2
- PMEL | c.8T>G p.L3R | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.221); catalogued as COSV99906703; called by muse, mutect2, varscan2
- PNKP | c.46C>A p.P16T | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100465107; called by muse, mutect2
- POLE | c.6073G>A p.V2025M | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.139); catalogued as rs995579204, COSV57684467; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POPDC2 | c.599A>C p.Q200P | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99950940; called by muse, mutect2
- POU2F2 | c.1073G>A p.C358Y (on ENST00000526816 / NM_001207025.3; = p.C342Y on NM_002698.5) | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as COSV100657320; called by muse, mutect2, varscan2
- POU4F1 | c.1160C>T p.A387V | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV65883943; called by muse, mutect2, varscan2
- POU4F2 | c.871G>A p.V291M | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs369337694; called by muse, varscan2
- PPEF1 | c.670C>A p.P224T | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100583672; called by muse, mutect2, varscan2
- PPID | c.385G>A p.G129S | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as rs143782344; called by muse, mutect2, varscan2
- PPIP5K2 | c.3713del p.N1238Tfs*35 (on ENST00000358359 / NM_001276277.3; = p.N1217Tfs*35 on NM_015216.5 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | catalogued as rs201392612; called by mutect2, varscan2
- PPL | c.2513A>C p.E838A | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as COSV100630670; called by muse, mutect2, varscan2
- PPM1D | c.1744C>T p.R582C | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.925); catalogued as COSV100010780; called by muse, mutect2, varscan2
- PPM1F | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs750380798, COSV54283325; called by muse, mutect2, varscan2
- PPOX | c.342del p.X114_splice | Splice Site (DEL) | VAF 10/90 reads (11%) | catalogued as CS0911074; called by mutect2, pindel
- PPP1R12A | c.1094C>T p.S365L | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs370507874; called by muse, mutect2, varscan2
- PPP1R12C | c.1058_1060del p.K353del | In Frame Del (DEL) | VAF 9/47 reads (19%) | catalogued as rs1301546955; called by pindel, varscan2
- PRAMEF1 | c.1189C>A p.L397M | Missense Mutation (SNP) | VAF 56/266 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs771823945, COSV100179627; called by muse, mutect2, varscan2
- PRAMEF20 | c.1154G>A p.R385H | Missense Mutation (SNP) | VAF 66/315 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.703); catalogued as rs965592462; called by muse, mutect2, varscan2
- PRICKLE1 | c.1288C>T p.P430S | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1311851345, COSV100566238; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRPS1 | c.763G>A p.G255S | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as rs1423101228, COSV65054535, COSV65054656; called by muse, mutect2, varscan2
- PRRG3 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.112); catalogued as COSV100948599; called by muse, mutect2, varscan2
- PRSS36 | c.2549C>A p.T850N | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.135); catalogued as COSV99191253; called by muse, mutect2, varscan2
- PRSS38 | c.26G>A p.G9D | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs771095640, COSV100816451; called by muse, mutect2, varscan2
- PRSS38 | c.312G>T p.R104S | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.07); catalogued as COSV100816453; called by muse, mutect2, varscan2
- PRX | c.2983C>T p.Q995* | Nonsense Mutation (SNP) | VAF 12/44 reads (27%) | catalogued as COSV99397633; called by muse, mutect2, varscan2
- PSG1 | c.565A>G p.M189V | Missense Mutation (SNP) | VAF 68/297 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs765252790, COSV99739547; called by muse, mutect2, varscan2
- PSKH1 | c.911G>A p.R304Q | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.183); catalogued as rs1279451077, COSV99344593; called by muse, mutect2, varscan2
- PSMC5 | c.233G>T p.R78L | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as COSV99856344; called by muse, mutect2, varscan2
- PTPN21 | c.3308C>T p.P1103L | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141951135; called by muse, mutect2, varscan2
- PTPN4 | c.1822G>A p.D608N | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.561); catalogued as rs750591561, COSV99749965; called by muse, mutect2, varscan2
- PTPRC | c.3646-1G>T p.X1216_splice | Splice Site (SNP) | VAF 9/52 reads (17%) | catalogued as COSV100722461; called by muse, mutect2, varscan2
- PTPRS | c.5640C>T p.C1880= | Splice Region (SNP) | VAF 22/105 reads (21%) | catalogued as COSV99510018; called by muse, mutect2
- PTPRS | c.1341G>A p.W447* | Nonsense Mutation (SNP) | VAF 24/95 reads (25%) | catalogued as COSV99510021; called by muse, mutect2, varscan2
- PYCARD | c.448C>T p.R150W | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as COSV99910906; called by muse, mutect2, varscan2
- QPCTL | c.1019A>G p.H340R | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99171251; called by muse, mutect2, varscan2
- QRICH1 | c.1214C>T p.T405M | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.586); catalogued as rs1206930424, COSV100676747; called by muse, mutect2, varscan2
- RAB15 | c.490C>A p.R164S (on ENST00000533601 / NM_001308154.2; = p.R207= on NM_198686.3) | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0.243); catalogued as COSV50825673, COSV99962069; called by muse, mutect2, varscan2
- RABGAP1 | c.2789dup p.N930Kfs*7 | Frame Shift Ins (INS) | VAF 26/126 reads (21%) | catalogued as rs749213218; called by mutect2, varscan2
- RADIL | c.1039C>A p.L347M | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as rs780869370, COSV101271346, COSV68200408; called by muse, mutect2, varscan2
- RAPGEF1 | c.911C>T p.A304V | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100940440; called by muse, mutect2, varscan2
- RASSF9 | c.679G>A p.G227R | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100771311, COSV63435387; called by muse, mutect2
- RBMX2 | c.866A>G p.Y289C | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs1378549079, COSV100564760; called by muse, mutect2, varscan2
- RBPJ | c.1351C>T p.R451W | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100623577; called by muse, mutect2, varscan2
- RDH16 | c.803T>C p.M268T | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as COSV100660092; called by muse, mutect2, varscan2
- RDH16 | c.609G>A p.M203I | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1323820345, COSV100660094; called by muse, mutect2, varscan2
- RELN | c.6739C>T p.L2247F | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.949); catalogued as COSV100633251; called by muse, mutect2
- RETREG2 | c.1120C>A p.R374S | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as COSV99811489; called by muse, mutect2, varscan2
- RFC1 | c.1288A>T p.I430F | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100567579; called by muse, mutect2, varscan2
- RFX2 | c.362C>A p.A121D | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.371); catalogued as COSV100353684; called by muse, mutect2, varscan2
- RGS2 | c.352G>T p.D118Y | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99343319, COSV99343447; called by muse, mutect2, varscan2
- RHO | c.811G>A p.V271M | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs201008735, COSV56214488; called by muse, mutect2, varscan2
- RIBC1 | c.473G>T p.G158V | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV99394927; called by muse, mutect2, varscan2
- RIC1 | c.1709G>A p.R570Q | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.733); catalogued as rs1456841422, COSV99317079; called by muse, mutect2, varscan2
- RIC1 | c.1992G>T p.Q664H | Missense Mutation (SNP) | VAF 49/161 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.79); catalogued as COSV99317084; called by muse, mutect2, varscan2
- RIMS1 | c.54del p.M19Cfs*7 | Frame Shift Del (DEL) | VAF 20/76 reads (26%) | catalogued as rs1378143186; called by mutect2, pindel, varscan2
- RIPK4 | c.1565C>T p.P522L (on ENST00000352483; = p.P474L on NM_020639.3) | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs970090763, COSV60186557; called by muse, mutect2, varscan2
- RNF10 | c.1894G>T p.V632F | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as COSV100378592; called by muse, mutect2, varscan2
- RNF123 | c.500C>T p.T167I | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV100570563; called by muse, mutect2, varscan2
- RNF20 | c.1480G>A p.V494I | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.956); catalogued as COSV66662281; called by muse, mutect2, varscan2
- RNF213 | c.6091G>A p.D2031N | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.168); catalogued as COSV100300224; called by muse, mutect2, varscan2
- ROR1 | c.1933T>C p.Y645H | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100935140; called by muse, mutect2, varscan2
- RP1L1 | c.4928T>C p.L1643P | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.071); catalogued as COSV101223146; called by muse, mutect2, varscan2
- RPL5 | c.567A>T p.E189D | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as COSV100240334; called by muse, mutect2, varscan2
- RPRD2 | c.2137A>G p.T713A | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV100955015; called by muse, mutect2
- RREB1 | c.3598G>A p.A1200T | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV100619277; called by muse, mutect2
- RTN1 | c.1654C>T p.R552W | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.332); catalogued as rs780650595, COSV50720798; called by muse, mutect2, varscan2
- RTN2 | c.652A>G p.T218A | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.068); catalogued as COSV99838861; called by muse, mutect2, varscan2
- RUNX1 | c.1247A>G p.N416S (on ENST00000344691 / NM_001001890.3; = p.N443S on NM_001754.5) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.27); catalogued as rs1376285640; called by mutect2, varscan2
- RUSC2 | c.2971C>T p.L991F | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV100770650; called by muse, mutect2, varscan2
- SAAL1 | c.702G>T p.Q234H | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV100253831; called by muse, mutect2, varscan2
- SALL1 | c.3432_3434del p.S1147del | In Frame Del (DEL) | VAF 25/78 reads (32%) | catalogued as rs1217562955; called by pindel, varscan2
- SALL3 | c.3769G>A p.A1257T | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101609977; called by muse, mutect2, varscan2
- SAT1 | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as rs1363595764, COSV63380787; called by muse, mutect2, varscan2
- SBF1 | c.3716T>C p.L1239P | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV100817651; called by muse, mutect2, varscan2
- SBNO2 | c.2287G>A p.G763R | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.209); catalogued as COSV100684386; called by muse, mutect2, varscan2
- SCCPDH | c.540C>G p.F180L | Missense Mutation (SNP) | VAF 74/161 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.208); catalogued as COSV100829720, COSV63619523; called by muse, mutect2, varscan2
- SCN1A | c.5192C>T p.A1731V (on ENST00000303395 / NM_001202435.3; = p.A1720V on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.636); catalogued as COSV57665601; called by muse, mutect2, varscan2
- SCN1A | c.2855G>T p.W952L (on ENST00000303395 / NM_001202435.3; = p.W941L on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/201 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as CM032360, COSV100320046, COSV57667747; called by muse, mutect2, varscan2
- SCN5A | c.2365G>A p.V789I | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as rs199473159, CM100673, COSV61115379; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN7A | c.2240dup p.N747Kfs*10 | Frame Shift Ins (INS) | VAF 18/92 reads (20%) | catalogued as rs1379314652; called by mutect2, pindel, varscan2
- SCPEP1 | c.944G>A p.G315D | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99227777; called by muse, mutect2, varscan2
- SDHA | c.1573G>A p.V525M | Missense Mutation (SNP) | VAF 35/173 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.959); catalogued as rs979815942, COSV99371155; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SDK1 | c.4759G>A p.A1587T | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as rs376337773, COSV101269170, COSV67364525; called by muse, mutect2, varscan2
- SEC23B | c.1324G>A p.V442I | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99357603; called by muse, mutect2, varscan2
- SELENOO | c.1267C>T p.R423C | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as rs780037215, COSV101096715; called by muse, mutect2, varscan2
- SEMA3D | c.1568G>A p.R523Q | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as rs770195185, COSV99406353; called by muse, mutect2, varscan2
- SENP6 | c.2527C>T p.Q843* | Nonsense Mutation (SNP) | VAF 8/47 reads (17%) | catalogued as COSV100894404; called by muse, mutect2, varscan2
- SEPTIN10 | c.601-2A>G p.X201_splice | Splice Site (SNP) | VAF 11/58 reads (19%) | catalogued as rs1333395747, COSV100453998; called by muse, mutect2
- SESN1 | c.1370G>T p.R457M (on ENST00000356644 / NM_001199933.1; = p.R516M on NM_014454.3) | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100122736; called by muse, mutect2, varscan2
- SEZ6L2 | c.59T>C p.L20P | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.38); catalogued as COSV100435314; called by muse, mutect2, varscan2
- SF3A2 | c.682C>A p.P228T | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.011); catalogued as rs775324908, COSV99677720; called by muse, mutect2, varscan2
- SF3A3 | c.19C>G p.Q7E | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.9); catalogued as COSV100885624; called by muse, mutect2, varscan2
- SF3B4 | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs1553765964, COSV99641079; called by muse, mutect2, varscan2
- SH2D3A | c.820C>T p.P274S | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV99837923; called by muse, mutect2
- SHC1 | c.1087del p.V363Wfs*2 (on ENST00000368445 / NM_183001.5; = p.V253Wfs*2 on NM_003029.5) | Frame Shift Del (DEL) | VAF 12/102 reads (12%) | catalogued as rs746556543; called by mutect2, varscan2
- SHPRH | c.495del p.E166Nfs*3 | Frame Shift Del (DEL) | VAF 12/68 reads (18%) | catalogued as rs1469942319; called by mutect2, varscan2
- SHQ1 | c.42C>A p.F14L | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.55); catalogued as COSV100344807; called by muse, mutect2, varscan2
- SIGLEC1 | c.2204C>T p.A735V | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.055); catalogued as rs138665604; called by muse, mutect2, varscan2
- SIK2 | c.1624A>G p.N542D | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.225); catalogued as COSV100516106; called by muse, mutect2, varscan2
- SKP2 | c.515A>G p.Q172R | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV99947991; called by muse, mutect2, varscan2
- SLA | c.382C>T p.Q128* (on ENST00000338087 / NM_001045556.3; = p.Q168* on NM_006748.4) | Nonsense Mutation (SNP) | VAF 12/52 reads (23%) | catalogued as COSV99600209; called by muse, mutect2, varscan2
- SLAMF1 | c.829del p.S277Afs*54 | Frame Shift Del (DEL) | VAF 42/230 reads (18%) | catalogued as rs751442558; called by mutect2, varscan2
- SLC13A3 | c.197C>A p.P66H | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99286501; called by muse, mutect2, varscan2
- SLC1A6 | c.1118T>C p.F373S | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); catalogued as COSV99693605; called by muse, mutect2, varscan2
- SLC25A47 | c.611G>A p.C204Y | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV100690126; called by muse, mutect2
- SLC26A6 | c.389T>A p.V130D | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99373236; called by muse, mutect2, varscan2
- SLC27A3 | c.2260-1G>T p.X754_splice (on ENST00000271857; = p.X626_splice on NM_024330.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 19/92 reads (21%) | catalogued as COSV99669881; called by muse, mutect2, varscan2
- SLC27A4 | c.1661C>T p.A554V | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.2); catalogued as COSV100307221; called by muse, mutect2, varscan2
- SLC30A6 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV99249548; called by muse, mutect2, varscan2
- SLC38A10 | c.1886del p.G629Dfs*76 (on ENST00000374759 / NM_001037984.3; = p.G629Dfs*? on NM_138570.4) | Frame Shift Del (DEL) | VAF 16/79 reads (20%) | catalogued as COSV55848724; called by mutect2, pindel, varscan2
- SLC4A11 | c.2128C>A p.L710M | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.739); catalogued as COSV101195932, COSV66261823; called by muse, mutect2, varscan2
- SLC4A3 | c.2652del p.S885Afs*22 | Frame Shift Del (DEL) | VAF 9/45 reads (20%) | catalogued as rs760972612; called by mutect2, pindel, varscan2
- SLC4A3 | c.3307C>T p.R1103C | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs375878653; called by muse, mutect2, varscan2
- SLC6A11 | c.664G>A p.G222R | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753638124, COSV99594361, COSV99594782; called by muse, mutect2, varscan2
- SLC9A3 | c.1312G>A p.V438I | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.656); catalogued as rs375784344; called by muse, mutect2, varscan2
- SLITRK4 | c.1283G>A p.R428H | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782819249, COSV62023474; called by muse, mutect2, varscan2
- SMC3 | c.3032A>G p.Y1011C | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV100699878; called by muse, mutect2, varscan2
- SMC6 | c.1180del p.S394Vfs*20 | Frame Shift Del (DEL) | VAF 8/62 reads (13%) | catalogued as rs761535042; called by mutect2, pindel, varscan2
- SNUPN | c.1080T>A p.N360K | Missense Mutation (SNP) | VAF 34/175 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); catalogued as COSV100419333; called by muse, mutect2, varscan2
- SNX29 | c.247+2T>C p.X83_splice | Splice Site (SNP) | VAF 14/59 reads (24%) | catalogued as COSV73829718; called by muse, mutect2, varscan2
- SOX5 | c.1947G>A p.M649I | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.876); catalogued as COSV100506568; called by muse, mutect2, varscan2
- SOX5 | c.1167T>C p.D389= | Splice Region (SNP) | VAF 10/48 reads (21%) | catalogued as COSV100506570; called by muse, mutect2, varscan2
- SOX7 | c.769del p.L257Wfs*14 | Frame Shift Del (DEL) | VAF 15/58 reads (26%) | catalogued as rs1478777952; called by mutect2, pindel, varscan2
- SPAG17 | c.6118C>T p.P2040S | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV60453629; called by muse, mutect2, varscan2
- SPAG5 | c.3047A>G p.H1016R | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.796); catalogued as COSV99881817; called by muse, mutect2, varscan2
- SPATA2L | c.1156C>T p.P386S | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs929911079, COSV99232214; called by muse, mutect2, varscan2
- SPP2 | c.29T>C p.M10T | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs756261230, COSV51445229; called by muse, mutect2, varscan2
- SPTA1 | c.2278G>A p.D760N | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.12); catalogued as COSV100934707, COSV104426846; called by muse, mutect2, varscan2
- SPTBN1 | c.3331A>T p.I1111F | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100442324; called by muse, mutect2, varscan2
- SPTY2D1 | c.1015C>T p.H339Y | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.188); catalogued as COSV100311604; called by muse, mutect2, varscan2
- SRP68 | c.694C>A p.L232M | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.984); catalogued as COSV100326052; called by muse, mutect2, varscan2
- SRPK1 | c.1460del p.N487Mfs*7 | Frame Shift Del (DEL) | VAF 11/53 reads (21%) | catalogued as rs1561978130; called by mutect2, pindel, varscan2
- SSC4D | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99299892; called by muse, mutect2, varscan2
- STC2 | c.587A>G p.Q196R | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as COSV99438279; called by muse, mutect2, varscan2
- STMN1 | c.442G>T p.A148S | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV100771277; called by muse, mutect2, varscan2
- STRADB | c.985C>T p.R329* | Nonsense Mutation (SNP) | VAF 32/195 reads (16%) | catalogued as rs1296107131, COSV99524441, COSV99524718; called by muse, mutect2, varscan2
- STRADB | c.1148T>G p.L383R | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as COSV99524443; called by muse, mutect2, varscan2
- STRN4 | c.1906+2T>C p.X636_splice | Splice Site (SNP) | VAF 12/74 reads (16%) | catalogued as COSV99623538; called by muse, mutect2, varscan2
- SULF1 | c.298G>A p.V100M | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.233); catalogued as COSV99482756; called by muse, mutect2, varscan2
- SUPT6H | c.920G>T p.G307V | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV100112270; called by muse, mutect2, varscan2
- SWAP70 | c.341A>C p.D114A | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV100013691; called by muse, mutect2, varscan2
- SYCE1 | c.851del p.K284Sfs*29 (on ENST00000343131 / NM_001143764.3; = p.K248Sfs*31 on NM_130784.3) | Frame Shift Del (DEL) | VAF 18/86 reads (21%) | catalogued as COSV100385992; called by mutect2, pindel, varscan2
- SYCP2 | c.3949C>A p.L1317M | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as COSV100698146; called by muse, mutect2, varscan2
- SYK | c.720A>G p.L240= | Splice Region (SNP) | VAF 31/139 reads (22%) | catalogued as COSV101002400; called by muse, mutect2, varscan2
- SYN2 | c.1009A>G p.T337A | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated (0.78); PolyPhen benign (0.113); catalogued as COSV101413863; called by muse, mutect2, varscan2
- SYNJ1 | c.1297C>T p.Q433* | Nonsense Mutation (SNP) | VAF 13/41 reads (32%) | catalogued as COSV100449169; called by muse, mutect2, varscan2
- TBC1D10C | c.960del p.A321Rfs*100 | Frame Shift Del (DEL) | VAF 17/96 reads (18%) | catalogued as rs751687887; called by mutect2, pindel, varscan2
- TBC1D8 | c.1344G>A p.M448I | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100964389; called by muse, mutect2, varscan2
- TBK1 | c.37G>A p.D13N | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100225452; called by muse, mutect2, varscan2
- TBK1 | c.38A>T p.D13V | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100225453; called by muse, mutect2, varscan2
- TBK1 | c.1567G>C p.D523H | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.049); catalogued as COSV100538116, COSV100538419; called by muse, mutect2, varscan2
- TCF20 | c.3307G>A p.G1103S | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs762509400, COSV100166444; called by muse, mutect2, varscan2
- TCF7L1 | c.742del p.L248Sfs*29 | Frame Shift Del (DEL) | VAF 15/65 reads (23%) | catalogued as COSV56399337; called by mutect2, pindel, varscan2
- TCHH | c.1046A>T p.Q349L | Missense Mutation (SNP) | VAF 30/210 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.012); catalogued as COSV100914966; called by muse, mutect2, varscan2
- TDGF1 | c.454C>A p.L152I | Missense Mutation (SNP) | VAF 36/151 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.045); catalogued as COSV99947338; called by muse, mutect2, varscan2
- TET2 | c.394A>G p.N132D | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.537); catalogued as COSV99482217; called by muse, mutect2, varscan2
- TEX14 | c.3377-2A>G p.X1126_splice (on ENST00000240361 / NM_001201457.2; = p.X1080_splice on NM_031272.5) | Splice Site (SNP) | VAF 5/41 reads (12%) | catalogued as COSV99541937; called by muse, mutect2
- TFCP2 | c.565-1G>T p.X189_splice | Splice Site (SNP) | VAF 18/92 reads (20%) | catalogued as COSV56937546; called by muse, mutect2, varscan2
- TG | c.1670A>G p.N557S | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.656); catalogued as COSV99600206; called by muse, mutect2, varscan2
- TGM2 | c.733T>A p.Y245N | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100821579; called by muse, mutect2, varscan2
- THAP11 | c.89C>A p.A30D | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.344); catalogued as COSV99534358; called by muse, mutect2, varscan2
- THBS3 | c.914del p.P305Lfs*181 | Frame Shift Del (DEL) | VAF 12/82 reads (15%) | catalogued as rs757853564; called by mutect2, pindel, varscan2
- THEMIS | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.023); catalogued as rs1388326811, COSV100965326; called by muse, mutect2, varscan2
- THG1L | c.75A>T p.R25S | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV99180236; called by muse, mutect2, varscan2
- THSD1 | c.2038G>A p.A680T | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as rs1340148546, COSV99318833; called by muse, mutect2, varscan2
- THSD4 | c.1475G>A p.S492N | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99965117; called by muse, mutect2, varscan2
- TK2 | c.97G>A p.V33I (on ENST00000299697; = p.V89I on NM_004614.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.038); catalogued as COSV100228085; called by muse, mutect2, varscan2
- TLN1 | c.7515G>T p.Q2505H | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59206572, COSV59211744; called by muse, mutect2, varscan2
- TLR1 | c.2255G>T p.R752M | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV100458429; called by muse, mutect2, varscan2
- TMEM132A | c.454C>A p.P152T | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.663); catalogued as COSV99134714; called by muse, mutect2
- TMEM260 | c.332dup p.T112Hfs*36 | Frame Shift Ins (INS) | VAF 31/136 reads (23%) | catalogued as rs772774176; called by mutect2, varscan2
- TMOD3 | c.282del p.I97Yfs*23 | Frame Shift Del (DEL) | VAF 22/100 reads (22%) | catalogued as rs759399045; called by mutect2, varscan2
- TMPRSS15 | c.2908del p.D970Ifs*6 | Frame Shift Del (DEL) | VAF 11/54 reads (20%) | catalogued as COSV53037014; called by mutect2, pindel, varscan2
- TNIK | c.3259C>T p.R1087* | Nonsense Mutation (SNP) | VAF 10/54 reads (19%) | catalogued as rs1383219718, COSV99456545; called by muse, mutect2, varscan2
- TNN | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs895808761, COSV99511669; called by muse, mutect2
- TP53BP1 | c.2130del p.E711Nfs*12 | Frame Shift Del (DEL) | VAF 11/66 reads (17%) | catalogued as rs1375740992, COSV55498775; called by mutect2, pindel, varscan2
- TRANK1 | c.4366C>T p.R1456W | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs559712651, COSV100082431; called by muse, mutect2, varscan2
- TREH | c.1052C>T p.A351V | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); catalogued as COSV99874351; called by muse, mutect2, varscan2
- TREX2 | c.292C>T p.R98W (on ENST00000334497; = p.R55W on NM_080701.3) | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); catalogued as rs1246468102, COSV100444071, COSV57848581; called by muse, mutect2, varscan2
- TRIM10 | c.1120G>A p.A374T | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.371); catalogued as COSV100939676; called by muse, mutect2, varscan2
- TRIM45 | c.1093C>T p.R365C | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.386); catalogued as rs1419216570, COSV99868398; called by muse, mutect2, varscan2
- TRIM68 | c.386A>G p.H129R | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100331687; called by muse, mutect2, varscan2
- TRPM2 | c.568T>A p.F190I | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100308563; called by muse, mutect2, varscan2
- TRPM8 | c.2788A>G p.T930A | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV100223882; called by muse, mutect2
- TRRAP | c.100+1G>A p.X34_splice | Splice Site (SNP) | VAF 10/36 reads (28%) | catalogued as rs1562922048, COSV100722317; called by muse, mutect2, varscan2
- TSPOAP1 | c.2152G>A p.V718M | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99270745; called by muse, mutect2, varscan2
- TSR1 | c.697C>T p.L233F | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99280011; called by muse, mutect2, varscan2
- TTN | c.78934C>G p.P26312A (on ENST00000591111; = p.P18888A on NM_003319.4) | Missense Mutation (SNP) | VAF 19/82 reads (23%) | PolyPhen probably damaging (0.982); catalogued as COSV100605111, COSV100611994; called by muse, mutect2, varscan2
- TTN | c.65835A>C p.K21945N (on ENST00000591111; = p.K14521N on NM_003319.4) | Missense Mutation (SNP) | VAF 16/92 reads (17%) | PolyPhen probably damaging (0.997); catalogued as COSV100605112; called by muse, mutect2, varscan2
- TTN | c.37350A>G p.I12450M (on ENST00000591111; = p.I5026M on NM_003319.4) | Missense Mutation (SNP) | VAF 13/51 reads (25%) | PolyPhen probably damaging (0.931); catalogued as COSV100605114; called by muse, mutect2, varscan2
- TUBGCP2 | c.1588C>T p.H530Y | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as COSV99427520; called by muse, mutect2, varscan2
- TWF1 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.728); catalogued as COSV100286024; called by muse, mutect2, varscan2
- TXNDC16 | c.1297G>A p.A433T | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99909082; called by muse, mutect2, varscan2
- UBE2O | c.3262C>T p.R1088* | Nonsense Mutation (SNP) | VAF 19/94 reads (20%) | catalogued as COSV100039269; called by muse, mutect2, varscan2
- UBR4 | c.974G>A p.R325H | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1220926322, COSV64399665; called by muse, mutect2, varscan2
- UGT2A1 | c.715+2T>C p.X239_splice | Splice Site (SNP) | VAF 15/69 reads (22%) | catalogued as COSV54142180; called by muse, mutect2, varscan2
- UGT2B10 | c.698A>G p.Q233R | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV99608138; called by muse, mutect2, varscan2
515 further variants in this file (196 protein-altering or splice-affecting, 291 silent, 28 other) are not listed here.
